Somatic mutation profile of tumor specimen C3L-08635-01 (aliquot CPT0481700006) from CPTAC case C3L-08635, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G1; Age at diagnosis: 67.4 years (24,606 days).
Specimen C3L-08635-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pylorus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9cbe5d2b-bf7b-4ce1-8011-0268015e179f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-08635-31 (Blood Derived Normal), aliquot CPT0481760002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/13d4bdaa-edcd-4964-916f-7698c1e4c6a8

The open-access MAF lists 3,032 somatic variants for this specimen: 2,236 protein-altering or splice-affecting, 670 silent, 126 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,506, Silent 670, Frame Shift Del 522, Frame Shift Ins 97, Intron 73, Nonsense Mutation 60, In Frame Del 22, 3'UTR 19, Splice Region 17, 5'Flank 10, 5'UTR 9, RNA 8.

Variants (750 of 3,032; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA4 | c.5463G>A p.T1821= | Splice Region (SNP) | VAF 83/225 reads (37%) | catalogued as rs367857935; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ABCC6 | c.855C>T p.T285= | Silent (SNP) | VAF 141/535 reads (26%) | catalogued as rs4780605; ClinVar: pathogenic / likely benign; called by muse, mutect2
- ATP6V1B1 | c.1155del p.I386Sfs*10 | Frame Shift Del (DEL) | VAF 70/259 reads (27%) | catalogued as rs781969081; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- AXIN2 | c.1994del p.G665Afs*24 | Frame Shift Del (DEL) | VAF 131/496 reads (26%) | catalogued as rs267606674; ClinVar: likely pathogenic / pathogenic; called by pindel, varscan2
- BRIP1 | c.2947del p.I983Lfs*2 | Frame Shift Del (DEL) | VAF 79/245 reads (32%) | catalogued as rs774684620; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- CHD8 | c.5607del p.D1870Tfs*21 (on ENST00000646647 / NM_001170629.2; = p.D1591Tfs*21 on NM_020920.4) | Frame Shift Del (DEL) | VAF 91/305 reads (30%) | catalogued as rs774152851; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- DNAH5 | c.5563dup p.I1855Nfs*6 | Frame Shift Ins (INS) | VAF 71/303 reads (23%) | catalogued as rs752925056; ClinVar: pathogenic; called by mutect2, varscan2
- ERBB2 | c.412C>T p.R138W | Missense Mutation (SNP) | VAF 101/267 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs779156384, COSV54070747; called by muse, mutect2, varscan2
- ESRP2 | c.974G>A p.R325H (on ENST00000565858 / NM_001365264.1; = p.R315H on NM_024939.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 131/331 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751873605, COSV52172250; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- EYS | c.179del p.L60Wfs*3 | Frame Shift Del (DEL) | VAF 94/353 reads (27%) | catalogued as rs786205652, CD157904; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- FERMT1 | c.676del p.Q226Sfs*26 | Frame Shift Del (DEL) | VAF 131/462 reads (28%) | catalogued as rs748240859, COSV54090339; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- FLNB | c.1592dup p.H532Tfs*9 | Frame Shift Ins (INS) | VAF 52/226 reads (23%) | catalogued as rs746105983; ClinVar: pathogenic; called by mutect2, varscan2
- INPP5E | c.1861C>T p.R621W | Missense Mutation (SNP) | VAF 107/331 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs142759730, CM1310190; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- IQSEC2 | c.4419dup p.S1474Qfs*133 | Frame Shift Ins (INS) | VAF 55/92 reads (60%) | catalogued as rs1569290954; ClinVar: pathogenic; called by mutect2, varscan2
- IQSEC2 | c.848del p.G283Afs*23 (on ENST00000642864 / NM_001111125.3; = p.G78Afs*23 on NM_015075.2) | Frame Shift Del (DEL) | VAF 183/268 reads (68%) | catalogued as rs782660318, COSV64726734; ClinVar: pathogenic; called by mutect2, varscan2
- KMT2B | c.521dup p.T176Dfs*8 | Frame Shift Ins (INS) | VAF 265/631 reads (42%) | catalogued as rs763183959; ClinVar: pathogenic; called by mutect2, varscan2
- MAGI2 | c.1808T>G p.L603R | Missense Mutation (SNP) | VAF 124/374 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV62636665, COSV62664406; called by muse, varscan2
- MLH1 | c.62C>T p.A21V | Missense Mutation (SNP) | VAF 56/342 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.849); catalogued as rs63750706, CM044666, CM122664; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NF1 | c.2033del p.P678Rfs*10 | Frame Shift Del (DEL) | VAF 89/281 reads (32%) | catalogued as rs587781807, CX1511110; ClinVar: pathogenic; called by pindel, varscan2
- NPHS2 | c.467del p.L156Cfs*25 | Frame Shift Del (DEL) | VAF 70/202 reads (35%) | catalogued as rs528833893, CD042219; ClinVar: uncertain significance / pathogenic; called by mutect2, varscan2
- PCCA | c.923del p.L308Wfs*14 | Frame Shift Del (DEL) | VAF 44/183 reads (24%) | catalogued as rs573607437; ClinVar: pathogenic; called by mutect2, varscan2
- PKD1 | c.2494dup p.R832Pfs*40 | Frame Shift Ins (INS) | VAF 149/470 reads (32%) | catalogued as rs1567210630; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- RSRC1 | c.268C>T p.R90* | Nonsense Mutation (SNP) | VAF 152/233 reads (65%) | catalogued as rs1183090232, COSV55823761; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SMCHD1 | c.1655G>A p.R552Q | Missense Mutation (SNP) | VAF 46/162 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs886042392; ClinVar: pathogenic / uncertain significance; called by muse, mutect2, varscan2
- TBCK | c.1370dup p.N457Kfs*10 (on ENST00000273980 / NM_001163436.4; = p.N394Kfs*10 on NM_033115.5 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 66/168 reads (39%) | catalogued as rs746860249; ClinVar: pathogenic; called by mutect2, varscan2
- TTN | c.101706del p.A33903Pfs*2 (on ENST00000591111; = p.A26479Pfs*2 on NM_003319.4) | Frame Shift Del (DEL) | VAF 73/251 reads (29%) | catalogued as rs869312069, CD1514610; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- ZNF469 | c.10248del p.R3417Gfs*56 (on ENST00000437464; = p.R3445Gfs*56 on NM_001367624.2) | Frame Shift Del (DEL) | VAF 154/472 reads (33%) | catalogued as rs764470052, COSV99081573; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- AARD | c.194G>A p.R65H | Missense Mutation (SNP) | VAF 158/758 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as COSV100991995; called by muse, varscan2
- ABCA4 | c.4705G>A p.V1569I | Missense Mutation (SNP) | VAF 111/342 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs373023236, COSV64676456; called by muse, mutect2, varscan2
- ABCA9 | c.2769G>A p.G923= | Splice Region (SNP) | VAF 68/214 reads (32%) | catalogued as COSV60625779; called by muse, mutect2, varscan2
- ABCB11 | c.3767C>T p.T1256M | Missense Mutation (SNP) | VAF 109/333 reads (33%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.882); catalogued as rs763244136; called by muse, mutect2, varscan2
- ABCB9 | c.634G>A p.A212T | Missense Mutation (SNP) | VAF 119/388 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.802); catalogued as rs780094868, COSV54893846; called by muse, mutect2, varscan2
- ABHD1 | c.478C>T p.R160W | Missense Mutation (SNP) | VAF 118/352 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.107); catalogued as rs769974946; called by muse, mutect2, varscan2
- ABRAXAS1 | c.331A>G p.T111A | Missense Mutation (SNP) | VAF 84/307 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58949311; called by muse, mutect2, varscan2
- AC004593.2 | c.66G>A p.W22* | Nonsense Mutation (SNP) | VAF 91/437 reads (21%) | catalogued as rs1254391966; called by muse, mutect2, varscan2
- ACD | c.784C>T p.R262W (on ENST00000620338; = p.R173W on NM_022914.3) | Missense Mutation (SNP) | VAF 130/411 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.663); catalogued as rs758515562, COSV54667269; called by muse, mutect2, varscan2
- ACLY | c.2185C>T p.R729W | Missense Mutation (SNP) | VAF 16/414 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.663); catalogued as rs782017025; called by muse, mutect2
- ACO2 | c.58T>C p.Y20H | Missense Mutation (SNP) | VAF 71/322 reads (22%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.497); catalogued as COSV53445410; called by muse, mutect2, varscan2
- ACOT11 | c.656G>A p.R219H | Missense Mutation (SNP) | VAF 106/348 reads (30%) | SIFT tolerated (0.34); PolyPhen benign (0.124); catalogued as rs199698636; called by muse, varscan2
- ADAM28 | c.224del p.N75Tfs*53 | Frame Shift Del (DEL) | VAF 26/117 reads (22%) | catalogued as rs570442888; called by mutect2, varscan2
- ADAMTS14 | c.2455del p.R819Afs*94 | Frame Shift Del (DEL) | VAF 103/301 reads (34%) | catalogued as COSV64605790; called by mutect2, pindel, varscan2
- ADAMTS9 | c.637del p.Q213Rfs*42 | Frame Shift Del (DEL) | VAF 93/351 reads (26%) | catalogued as rs1559825709, COSV55789887; called by mutect2, pindel, varscan2
- ADARB2 | c.269G>A p.R90Q | Missense Mutation (SNP) | VAF 143/398 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.136); catalogued as rs568793305; called by muse, mutect2, varscan2
- ADCY3 | c.2626G>A p.D876N | Missense Mutation (SNP) | VAF 80/283 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.091); catalogued as rs773980429; called by muse, mutect2, varscan2
- ADGRG2 | c.1570C>A p.P524T (on ENST00000379869 / NM_001079858.3; = p.P521T on NM_005756.4) | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT tolerated (0.42); PolyPhen benign (0.109); catalogued as COSV61337277, COSV61341357; called by muse, mutect2
- ADH6 | c.493G>A p.A165T | Missense Mutation (SNP) | VAF 118/362 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs61755961, COSV52955791; called by muse, mutect2, varscan2
- ADNP2 | c.2779A>G p.T927A | Missense Mutation (SNP) | VAF 60/351 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51540847; called by muse, mutect2, varscan2
- ADRA2B | c.580C>T p.R194C | Missense Mutation (SNP) | VAF 139/422 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV101337398, COSV69787824; called by muse, mutect2, varscan2
- ADRB3 | c.110C>T p.A37V | Missense Mutation (SNP) | VAF 223/611 reads (36%) | SIFT tolerated (0.64); PolyPhen benign (0.015); catalogued as rs919039334, COSV61462093; called by muse, mutect2, varscan2
- AFF2 | c.2425T>G p.L809V | Missense Mutation (SNP) | VAF 155/232 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV53986588; called by muse, mutect2, varscan2
- AHCTF1 | c.3885del p.K1295Nfs*11 (on ENST00000366508; = p.K1269Nfs*11 on NM_015446.5) | Frame Shift Del (DEL) | VAF 68/274 reads (25%) | catalogued as COSV58251593; called by mutect2, pindel, varscan2
- AHNAK | c.14257C>A p.P4753T | Missense Mutation (SNP) | VAF 96/504 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99947206; called by muse, mutect2, varscan2
- AK8 | c.36del p.E13Rfs*14 | Frame Shift Del (DEL) | VAF 90/304 reads (30%) | catalogued as rs757477831; called by mutect2, varscan2
- AKAP8 | c.1139C>T p.T380M | Missense Mutation (SNP) | VAF 96/399 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs140071691; called by muse, varscan2
- AKAP9 | c.116del p.K39Rfs*17 | Frame Shift Del (DEL) | VAF 120/370 reads (32%) | catalogued as COSV62339755; called by mutect2, varscan2
- AKT1S1 | c.495del p.T166Pfs*87 (on ENST00000344175 / NM_001098633.4; = p.T186Pfs*87 on NM_032375.5) | Frame Shift Del (DEL) | VAF 82/511 reads (16%) | catalogued as rs748776119, COSV59276444; called by mutect2, varscan2
- AL117339.4 | c.355C>T p.Q119* | Nonsense Mutation (SNP) | VAF 68/256 reads (27%) | catalogued as rs1409167513; called by muse, mutect2, varscan2
- AL139011.2 | c.443del p.F148Sfs*12 | Frame Shift Del (DEL) | VAF 100/276 reads (36%) | catalogued as rs1434377344; called by mutect2, varscan2
- ALDH4A1 | c.1567dup p.A523Gfs*8 | Frame Shift Ins (INS) | VAF 90/270 reads (33%) | catalogued as rs754334877; called by mutect2, varscan2
- ALKBH4 | c.485G>A p.R162Q | Missense Mutation (SNP) | VAF 149/387 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs955850961; called by muse, mutect2, varscan2
- AMER1 | c.81del p.G28Efs*25 | Frame Shift Del (DEL) | VAF 150/226 reads (66%) | catalogued as COSV100365453; called by mutect2, varscan2
- AMH | c.272G>A p.R91H | Missense Mutation (SNP) | VAF 196/694 reads (28%) | SIFT tolerated (0.78); PolyPhen benign (0.003); catalogued as rs534377664, COSV55553377, COSV55555643; called by muse, mutect2, varscan2
- AMIGO2 | c.1109G>A p.R370H | Missense Mutation (SNP) | VAF 108/345 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.029); catalogued as rs527243356, COSV56975299; called by muse, mutect2, varscan2
- AMPH | c.1745C>T p.P582L | Missense Mutation (SNP) | VAF 174/638 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs764013614, COSV100342559; called by muse, mutect2
- AMPH | c.1177C>T p.Q393* | Nonsense Mutation (SNP) | VAF 54/273 reads (20%) | catalogued as rs762654210; called by muse, mutect2, varscan2
- ANGPTL1 | c.1134dup p.V379Sfs*13 | Frame Shift Ins (INS) | VAF 84/346 reads (24%) | catalogued as rs775978569; called by mutect2, pindel, varscan2
- ANGPTL7 | c.557G>A p.R186Q | Missense Mutation (SNP) | VAF 155/426 reads (36%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.518); catalogued as rs146246137, COSV100816605; called by muse, mutect2, varscan2
- ANK2 | c.972del p.L325Cfs*24 | Frame Shift Del (DEL) | VAF 82/318 reads (26%) | catalogued as COSV100001787; called by mutect2, pindel, varscan2
- ANK3 | c.7076A>G p.Y2359C | Missense Mutation (SNP) | VAF 41/249 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.498); catalogued as rs958966819; called by muse, mutect2, varscan2
- ANKIB1 | c.2413A>G p.S805G | Missense Mutation (SNP) | VAF 111/329 reads (34%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.003); catalogued as rs775363363, COSV56059204; called by muse, mutect2, varscan2
- ANKRD11 | c.3180del p.D1061Ifs*257 | Frame Shift Del (DEL) | VAF 89/274 reads (32%) | catalogued as COSV56355463; called by mutect2, pindel, varscan2
- ANKRD31 | c.1533del p.G512Vfs*20 | Frame Shift Del (DEL) | VAF 117/253 reads (46%) | catalogued as rs1279723268; called by mutect2, pindel, varscan2
- ANKRD62 | c.1439del p.K480Sfs*5 | Frame Shift Del (DEL) | VAF 34/157 reads (22%) | catalogued as rs774510795; called by mutect2, varscan2
- ANOS1 | c.482A>C p.K161T | Missense Mutation (SNP) | VAF 159/238 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52916948, COSV52917470; called by muse, mutect2, varscan2
- ANXA13 | c.451del p.I151Sfs*20 | Frame Shift Del (DEL) | VAF 66/280 reads (24%) | catalogued as rs759218332; called by mutect2, varscan2
- AP1G1 | c.1091G>A p.R364H | Missense Mutation (SNP) | VAF 68/206 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100250083; called by muse, mutect2, varscan2
- APC2 | c.4787C>T p.A1596V | Missense Mutation (SNP) | VAF 362/693 reads (52%) | SIFT tolerated (0.08); PolyPhen benign (0.076); catalogued as rs1295278938; called by muse, mutect2, varscan2
- APOB | c.6661A>G p.N2221D | Missense Mutation (SNP) | VAF 49/176 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.231); catalogued as COSV51927234; called by muse, mutect2, varscan2
- APOL6 | c.646G>A p.V216M | Missense Mutation (SNP) | VAF 147/436 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.025); catalogued as rs145863080; called by muse, mutect2, varscan2
- APOL6 | c.934G>A p.E312K | Missense Mutation (SNP) | VAF 150/458 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.031); catalogued as rs780403475, COSV68749391; called by muse, mutect2, varscan2
- ARAP2 | c.913C>T p.R305C | Missense Mutation (SNP) | VAF 72/191 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.53); catalogued as rs776369290, COSV58281912; called by muse, mutect2, varscan2
- ARFGEF1 | c.4655dup p.P1553Tfs*7 | Frame Shift Ins (INS) | VAF 92/442 reads (21%) | catalogued as rs774148781; called by mutect2, varscan2
- ARHGAP22 | c.2072C>T p.A691V | Missense Mutation (SNP) | VAF 70/256 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.058); catalogued as COSV50965752; called by muse, mutect2, varscan2
- ARHGAP33 | c.682C>T p.R228W | Missense Mutation (SNP) | VAF 61/519 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.966); catalogued as rs766751884, COSV99138475; called by muse, mutect2, varscan2
- ARHGAP33 | c.1477C>T p.R493W | Missense Mutation (SNP) | VAF 98/699 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs143998454; called by muse, mutect2, varscan2
- ARHGAP33 | c.2680del p.L894Wfs*118 | Frame Shift Del (DEL) | VAF 319/721 reads (44%) | catalogued as rs746612565; called by mutect2, pindel, varscan2
- ARHGAP39 | c.1095del p.S366Rfs*18 | Frame Shift Del (DEL) | VAF 196/472 reads (42%) | catalogued as rs751388541; called by mutect2, varscan2
- ARHGEF40 | c.3460C>A p.R1154S | Missense Mutation (SNP) | VAF 88/296 reads (30%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.764); catalogued as rs772243335; called by muse, mutect2, varscan2
- ARID1B | c.521del p.P174Rfs*6 | Frame Shift Del (DEL) | VAF 119/419 reads (28%) | catalogued as rs1562376341; called by mutect2, pindel, varscan2
- ARID3A | c.1253C>T p.A418V | Missense Mutation (SNP) | VAF 184/600 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.787); catalogued as rs751888436, COSV55043024; called by muse, mutect2, varscan2
- ARMC8 | c.496T>C p.Y166H (on ENST00000469044 / NM_001363941.2; = p.Y152H on NM_014154.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 81/220 reads (37%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.969); catalogued as COSV61768458; called by muse, mutect2, varscan2
- ARMH2 | c.136del p.I46Sfs*20 | Frame Shift Del (DEL) | VAF 112/342 reads (33%) | catalogued as rs965020534; called by mutect2, varscan2
- ARSA | c.600G>T p.E200D | Missense Mutation (SNP) | VAF 180/533 reads (34%) | SIFT tolerated (0.49); PolyPhen benign (0.038); catalogued as COSV104368807; called by muse, mutect2, varscan2
- ARSF | c.1511dup p.L505Sfs*24 | Frame Shift Ins (INS) | VAF 134/245 reads (55%) | catalogued as rs781134306; called by mutect2, pindel, varscan2
- ARSG | c.1314G>T p.R438S | Missense Mutation (SNP) | VAF 84/235 reads (36%) | SIFT tolerated (0.57); PolyPhen benign (0.024); catalogued as COSV100048545; called by muse, mutect2, varscan2
- ARSI | c.1427A>G p.D476G | Missense Mutation (SNP) | VAF 156/495 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60817147; called by muse, mutect2, varscan2
- ART5 | c.679dup p.H227Pfs*2 | Frame Shift Ins (INS) | VAF 110/326 reads (34%) | catalogued as rs748137393; called by mutect2, varscan2
- ASB16 | c.686A>G p.Y229C | Missense Mutation (SNP) | VAF 164/515 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1181137194; called by muse, mutect2, varscan2
- ASCC2 | c.223G>A p.D75N | Missense Mutation (SNP) | VAF 136/331 reads (41%) | SIFT tolerated (0.16); PolyPhen benign (0.024); catalogued as rs772979948, COSV57072978; called by muse, mutect2, varscan2
- ASH1L | c.4810A>G p.T1604A | Missense Mutation (SNP) | VAF 154/371 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.038); catalogued as COSV64205832; called by muse, mutect2, varscan2
- ASXL3 | c.6110del p.P2037Hfs*43 | Frame Shift Del (DEL) | VAF 42/125 reads (34%) | catalogued as rs747712363; called by mutect2, varscan2
- ATAD2 | c.2323T>A p.F775I | Missense Mutation (SNP) | VAF 56/318 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV54878350; called by muse, mutect2
- ATAD2B | c.1404del p.F468Lfs*9 | Frame Shift Del (DEL) | VAF 122/430 reads (28%) | catalogued as rs866490133; called by mutect2, pindel, varscan2
- ATP10D | c.1222G>A p.D408N | Missense Mutation (SNP) | VAF 101/330 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.094); catalogued as COSV56710677; called by mutect2, varscan2
- ATP1A4 | c.88del p.M30Wfs*2 | Frame Shift Del (DEL) | VAF 114/389 reads (29%) | catalogued as rs769261788; called by mutect2, pindel, varscan2
- ATP2A1 | c.958G>A p.A320T | Missense Mutation (SNP) | VAF 68/235 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs766101847; called by muse, mutect2, varscan2
- ATP2B1 | c.1885C>T p.R629C | Missense Mutation (SNP) | VAF 101/321 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV53814233; called by muse, mutect2, varscan2
- ATP2B4 | c.2024G>A p.R675H | Missense Mutation (SNP) | VAF 55/188 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774551939; called by muse, mutect2, varscan2
- ATP4A | c.1720_1722del p.K574del | In Frame Del (DEL) | VAF 171/378 reads (45%) | catalogued as rs768505859; called by mutect2, pindel, varscan2
- ATP8B2 | c.1915G>T p.E639* (on ENST00000672630; = p.E606* on NM_001367934.1 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 149/430 reads (35%) | catalogued as rs1324497298; called by muse, mutect2, varscan2
- ATPAF1 | c.630del p.F210Lfs*2 (on ENST00000574428; = p.F233Lfs*2 on NM_022745.4) | Frame Shift Del (DEL) | VAF 84/341 reads (25%) | catalogued as rs1310890099, COSV61305396; called by pindel, varscan2
- ATXN3 | c.1110del p.K370Nfs*7 (on ENST00000545170; = p.K361Nfs*7 on NM_004993.6 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 42/147 reads (29%) | catalogued as rs776239444; called by mutect2, pindel, varscan2
- ATXN7 | c.119C>A p.P40Q | Missense Mutation (SNP) | VAF 72/216 reads (33%) | SIFT tolerated, low confidence (0.52); catalogued as rs1187351635; called by muse, varscan2
- B3GNT3 | c.22C>T p.R8W | Missense Mutation (SNP) | VAF 74/349 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.789); catalogued as rs202205669, COSV100592611; called by muse, mutect2, varscan2
- BABAM2 | c.488del p.N163Tfs*13 | Frame Shift Del (DEL) | VAF 52/173 reads (30%) | catalogued as COSV59620972; called by mutect2, varscan2
- BAHCC1 | c.5890G>C p.V1964L | Missense Mutation (SNP) | VAF 87/295 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs1474382768; called by muse, mutect2, varscan2
- BAP1 | c.839A>C p.Q280P | Missense Mutation (SNP) | VAF 133/423 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.091); catalogued as COSV56240069; called by muse, mutect2, varscan2
- BAZ1B | c.595C>T p.R199* | Nonsense Mutation (SNP) | VAF 56/218 reads (26%) | catalogued as rs1218654168; called by muse, varscan2
- BDP1 | c.938del p.L313* | Frame Shift Del (DEL) | VAF 80/200 reads (40%) | catalogued as rs752427670; called by mutect2, varscan2
- BPTF | c.598T>C p.Y200H | Missense Mutation (SNP) | VAF 84/260 reads (32%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV58841688; called by muse, varscan2
- BRCA1 | c.4046C>T p.T1349M | Missense Mutation (SNP) | VAF 99/470 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.107); catalogued as rs80357345; ClinVar: benign / likely benign / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- BRF1 | c.1561G>A p.A521T | Missense Mutation (SNP) | VAF 137/376 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1315588255, COSV59271311; called by muse, mutect2, varscan2
- BRINP3 | c.1511C>T p.T504M | Missense Mutation (SNP) | VAF 108/318 reads (34%) | SIFT tolerated (0.4); PolyPhen benign (0.062); catalogued as rs1209013098, COSV66538570; called by muse, mutect2, varscan2
- BRPF1 | c.1778G>A p.R593Q | Missense Mutation (SNP) | VAF 77/311 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.339); catalogued as rs745711133; called by muse, mutect2, varscan2
- BRWD1 | c.6926del p.L2309* | Frame Shift Del (DEL) | VAF 47/167 reads (28%) | catalogued as rs1455506786, COSV59000653; called by mutect2, pindel, varscan2
- BRWD1 | c.1258G>A p.E420K | Missense Mutation (SNP) | VAF 32/149 reads (21%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.678); catalogued as rs756501140; called by muse, mutect2, varscan2
- BTBD17 | c.527C>T p.A176V | Missense Mutation (SNP) | VAF 183/556 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1297469183, COSV64730926; called by muse, mutect2, varscan2
- BTBD6 | c.808C>T p.R270* | Nonsense Mutation (SNP) | VAF 133/460 reads (29%) | catalogued as rs749575989; called by muse, mutect2, varscan2
- BTRC | c.1780del p.R594Vfs*14 (on ENST00000370187 / NM_033637.4; = p.R558Vfs*14 on NM_003939.5) | Frame Shift Del (DEL) | VAF 111/366 reads (30%) | catalogued as rs774921343; called by mutect2, varscan2
- C1QL1 | c.65A>G p.Y22C | Missense Mutation (SNP) | VAF 96/286 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); catalogued as rs370315808; called by mutect2, varscan2
- C1QL3 | c.163C>A p.L55M | Missense Mutation (SNP) | VAF 163/438 reads (37%) | SIFT tolerated (0.19); PolyPhen benign (0.157); catalogued as COSV54348117; called by muse, mutect2, varscan2
- C2CD2 | c.368C>T p.A123V | Missense Mutation (SNP) | VAF 27/420 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.019); catalogued as rs201798564; called by muse, mutect2
- C2orf15 | c.4G>A p.G2R | Missense Mutation (SNP) | VAF 79/203 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs146177676; called by muse, mutect2, varscan2
- C2orf16 | c.4673G>A p.R1558H | Missense Mutation (SNP) | VAF 147/410 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs200091838; called by muse, mutect2, varscan2
- C3orf20 | c.2367del p.K790Sfs*9 | Frame Shift Del (DEL) | VAF 104/338 reads (31%) | catalogued as rs762124133; called by mutect2, pindel, varscan2
- C3orf33 | c.633del p.G212Efs*15 (on ENST00000340171 / NM_001308229.2; = p.G169Efs*15 on NM_173657.2) | Frame Shift Del (DEL) | VAF 55/201 reads (27%) | catalogued as rs762988845; called by mutect2, pindel, varscan2
- C4orf54 | c.4640del p.P1547Qfs*70 | Frame Shift Del (DEL) | VAF 89/265 reads (34%) | catalogued as rs763082793; called by mutect2, pindel, varscan2
- C4orf54 | c.4183C>T p.R1395W | Missense Mutation (SNP) | VAF 86/290 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs1480992885, COSV72766780; called by muse, mutect2, varscan2
- C9orf43 | c.523G>A p.A175T | Missense Mutation (SNP) | VAF 108/356 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs142991325, COSV55912773; called by muse, mutect2, varscan2
- C9orf72 | c.514A>G p.I172V | Missense Mutation (SNP) | VAF 63/184 reads (34%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as rs1563903707; called by muse, mutect2, varscan2
- CACNA1B | c.108del p.L37Cfs*64 | Frame Shift Del (DEL) | VAF 91/488 reads (19%) | catalogued as rs1474416938; called by mutect2, pindel, varscan2
- CACNA1C | c.4727-7C>T | Splice Region (SNP) | VAF 115/370 reads (31%) | catalogued as rs989372818; called by muse, mutect2, varscan2
- CACNA1I | c.3391C>T p.R1131C | Missense Mutation (SNP) | VAF 107/293 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.794); catalogued as rs1422369650; called by muse, mutect2, varscan2
- CACNA2D2 | c.2584C>T p.R862C (on ENST00000479441 / NM_001174051.3; = p.R855C on NM_006030.4) | Missense Mutation (SNP) | VAF 91/286 reads (32%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.764); catalogued as rs1302325175; called by muse, mutect2, varscan2
- CACNA2D4 | c.674A>G p.Y225C | Missense Mutation (SNP) | VAF 73/231 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs1460777510; called by muse, mutect2, varscan2
- CAPN15 | c.2134G>T p.G712C | Missense Mutation (SNP) | VAF 142/414 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54836453; called by muse, mutect2, varscan2
- CAPN3 | c.1070G>A p.R357Q | Missense Mutation (SNP) | VAF 97/419 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs988027905, CM050540, COSV58821731; ClinVar: conflicting interpretations of pathogenicity / uncertain significance; called by muse, mutect2, varscan2
- CARD14 | c.2192C>T p.A731V | Missense Mutation (SNP) | VAF 90/275 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs147578051; called by muse, mutect2, varscan2
- CARNS1 | c.460G>A p.E154K | Missense Mutation (SNP) | VAF 103/300 reads (34%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs962127378; called by muse, mutect2, varscan2
- CASZ1 | c.2068C>T p.R690C | Missense Mutation (SNP) | VAF 81/403 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100680625; called by muse, mutect2, varscan2
- CBFA2T2 | c.952C>T p.R318C | Missense Mutation (SNP) | VAF 70/243 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as rs146788442; called by muse, mutect2, varscan2
- CC2D1A | c.2807T>C p.L936P | Missense Mutation (SNP) | VAF 155/619 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs994729352; called by muse, mutect2, varscan2
- CCAR1 | c.1079C>T p.P360L | Missense Mutation (SNP) | VAF 96/304 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV56268573; called by muse, varscan2
- CCDC107 | c.467T>C p.I156T | Missense Mutation (SNP) | VAF 91/316 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as COSV100526230; called by muse, mutect2, varscan2
- CCDC14 | c.953G>A p.R318Q (on ENST00000488653; = p.R270Q on NM_022757.5) | Missense Mutation (SNP) | VAF 106/373 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs766062605, COSV100113456; called by muse, mutect2, varscan2
- CCDC141 | c.2170C>T p.R724* | Nonsense Mutation (SNP) | VAF 84/281 reads (30%) | catalogued as rs367700441, CM163738; called by muse, mutect2, varscan2
- CCDC149 | c.1300C>T p.R434C (on ENST00000635206 / NM_001330643.2; = p.R423C on NM_173463.5) | Missense Mutation (SNP) | VAF 118/365 reads (32%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.001); catalogued as rs1306185807; called by muse, mutect2, varscan2
- CCDC157 | c.898G>A p.A300T | Missense Mutation (SNP) | VAF 124/402 reads (31%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.536); catalogued as rs547209278; called by muse, mutect2, varscan2
- CCDC186 | c.632del p.K211Sfs*2 | Frame Shift Del (DEL) | VAF 36/130 reads (28%) | catalogued as COSV100991022; called by mutect2, pindel, varscan2
- CCDC42 | c.220C>A p.L74M | Missense Mutation (SNP) | VAF 85/235 reads (36%) | SIFT tolerated (0.26); PolyPhen benign (0.055); catalogued as COSV99549722; called by muse, mutect2, varscan2
- CCDC62 | c.2036del p.N679Ifs*18 | Frame Shift Del (DEL) | VAF 84/274 reads (31%) | catalogued as rs1053262354; called by mutect2, pindel, varscan2
- CCDC73 | c.1341del p.E448Kfs*5 | Frame Shift Del (DEL) | VAF 33/88 reads (38%) | catalogued as rs747079826; called by mutect2, varscan2
- CCDC86 | c.445del p.A149Pfs*33 | Frame Shift Del (DEL) | VAF 139/486 reads (29%) | catalogued as rs750855446; called by mutect2, pindel, varscan2
- CCDC88C | c.2230G>A p.V744M | Missense Mutation (SNP) | VAF 144/424 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.1); catalogued as rs955631018; called by muse, mutect2, varscan2
- CCDC9 | c.452G>A p.R151H | Missense Mutation (SNP) | VAF 215/407 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as rs767430070; called by muse, mutect2, varscan2
- CCNB3 | c.2755T>C p.S919P | Missense Mutation (SNP) | VAF 183/262 reads (70%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs1557214756; called by muse, mutect2, varscan2
- CD248 | c.34G>A p.A12T | Missense Mutation (SNP) | VAF 142/421 reads (34%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as rs774123813; called by muse, mutect2, varscan2
- CDAN1 | c.3193C>T p.R1065W | Missense Mutation (SNP) | VAF 130/438 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.629); catalogued as rs897669129; called by muse, mutect2, varscan2
- CDC14A | c.375del p.Y126Ifs*64 | Frame Shift Del (DEL) | VAF 159/307 reads (52%) | catalogued as rs773911500; called by mutect2, pindel, varscan2
- CDC34 | c.574G>A p.V192M | Missense Mutation (SNP) | VAF 120/487 reads (25%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.65); catalogued as rs774925566, COSV99198837; called by muse, mutect2, varscan2
- CDH10 | c.997A>G p.K333E | Missense Mutation (SNP) | VAF 40/226 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.218); catalogued as COSV52590382; called by muse, mutect2, varscan2
- CDH23 | c.4519C>T p.R1507W | Missense Mutation (SNP) | VAF 89/308 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.814); catalogued as rs760927863, COSV56477037; called by muse, mutect2, varscan2
- CDH3 | c.448del p.A150Qfs*11 | Frame Shift Del (DEL) | VAF 150/406 reads (37%) | catalogued as COSV50558023; called by mutect2, varscan2
- CDHR1 | c.553C>T p.R185C | Missense Mutation (SNP) | VAF 105/286 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); catalogued as rs768976866, COSV100259467; called by muse, mutect2, varscan2
- CDHR5 | c.1641dup p.G548Rfs*161 (on ENST00000358353 / NM_001171968.2; = p.G554Rfs*161 on NM_021924.5) | Frame Shift Ins (INS) | VAF 189/660 reads (29%) | catalogued as rs775160782; called by mutect2, pindel, varscan2
- CDK19 | c.1226C>T p.A409V | Missense Mutation (SNP) | VAF 186/564 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0.036); catalogued as rs1272012303; called by muse, mutect2, varscan2
- CDK9 | c.257G>A p.R86Q | Missense Mutation (SNP) | VAF 67/267 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.183); catalogued as rs371317161; called by muse, mutect2, varscan2
- CDKL1 | c.80C>T p.T27M | Missense Mutation (SNP) | VAF 98/401 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1481145094; called by muse, mutect2, varscan2
- CDKL2 | c.222del p.K74Nfs*5 | Frame Shift Del (DEL) | VAF 68/176 reads (39%) | catalogued as rs753353408; called by mutect2, varscan2
- CDKN2A | c.131A>G p.Y44C | Missense Mutation (SNP) | VAF 128/368 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.679); catalogued as rs1563892532, COSV100447081, COSV58696672, COSV58713866; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CDON | c.277G>A p.G93S | Missense Mutation (SNP) | VAF 120/358 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55001665; called by muse, mutect2, varscan2
- CDT1 | c.1339C>T p.R447W | Missense Mutation (SNP) | VAF 136/404 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as rs755342796, COSV56349586; called by muse, mutect2, varscan2
- CDX2 | c.661G>A p.A221T | Missense Mutation (SNP) | VAF 69/314 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.183); catalogued as rs773759361, COSV66829894; called by muse, varscan2
- CEBPE | c.836del p.G279Vfs*19 | Frame Shift Del (DEL) | VAF 99/344 reads (29%) | catalogued as rs1363394381, COSV52829926; called by mutect2, pindel, varscan2
- CELSR1 | c.5544dup p.T1849Dfs*23 | Frame Shift Ins (INS) | VAF 98/303 reads (32%) | catalogued as rs776824429; called by mutect2, varscan2
- CELSR2 | c.5533C>T p.R1845C | Missense Mutation (SNP) | VAF 162/478 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as rs745822210; called by muse, mutect2, varscan2
- CENPJ | c.824A>G p.E275G | Missense Mutation (SNP) | VAF 73/285 reads (26%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV67882950, COSV67883182; called by muse, mutect2, varscan2
- CEP350 | c.3982C>T p.R1328C | Missense Mutation (SNP) | VAF 111/343 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.73); catalogued as rs750054456, COSV62600955; called by muse, mutect2, varscan2
- CFAP299 | c.448del p.R150Dfs*9 | Frame Shift Del (DEL) | VAF 70/228 reads (31%) | catalogued as rs761800837; called by mutect2, varscan2
- CFAP97 | c.481del p.S161Afs*2 | Frame Shift Del (DEL) | VAF 114/343 reads (33%) | catalogued as rs34798240; called by mutect2, pindel, varscan2
- CFD | c.392G>A p.R131H | Missense Mutation (SNP) | VAF 154/646 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.446); catalogued as rs1453754353; called by muse, mutect2, varscan2
- CHD6 | c.6470C>T p.A2157V | Missense Mutation (SNP) | VAF 56/241 reads (23%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs552643669, COSV104428060; called by muse, mutect2, varscan2
- CHPF2 | c.1972del p.A658Lfs*3 | Frame Shift Del (DEL) | VAF 137/413 reads (33%) | catalogued as rs756745837; called by mutect2, pindel, varscan2
- CHRD | c.1969C>T p.R657C | Missense Mutation (SNP) | VAF 143/441 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.724); catalogued as rs1475546928, COSV52608510; called by muse, mutect2, varscan2
- CHTOP | c.65G>A p.R22H | Missense Mutation (SNP) | VAF 106/293 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.412); catalogued as COSV52680010; called by muse, mutect2, varscan2
- CIB4 | c.88T>C p.C30R | Missense Mutation (SNP) | VAF 82/277 reads (30%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs780966140; called by muse, mutect2, varscan2
- CKM | c.941G>A p.R314H | Missense Mutation (SNP) | VAF 102/431 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.941); catalogued as rs1313579937, COSV99488903; called by muse, mutect2, varscan2
- CLASP1 | c.1661G>A p.R554H | Missense Mutation (SNP) | VAF 99/297 reads (33%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as rs765350056; called by muse, mutect2, varscan2
- CLEC7A | c.259A>G p.R87G | Missense Mutation (SNP) | VAF 108/354 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs1417925295; called by muse, mutect2, varscan2
- CLIC4 | c.612del p.K204Nfs*11 | Frame Shift Del (DEL) | VAF 64/219 reads (29%) | catalogued as rs1175213607; called by mutect2, pindel, varscan2
- CLIP2 | c.42del p.K15Sfs*73 | Frame Shift Del (DEL) | VAF 152/494 reads (31%) | catalogued as COSV56275983; called by mutect2, pindel, varscan2
- CLIP2 | c.2278G>A p.E760K | Missense Mutation (SNP) | VAF 145/442 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.137); catalogued as rs374499437; called by muse, mutect2, varscan2
- CMTM7 | c.107T>C p.L36P | Missense Mutation (SNP) | VAF 97/327 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.466); catalogued as rs1389997557; called by muse, mutect2, varscan2
- CMYA5 | c.760A>G p.I254V | Missense Mutation (SNP) | VAF 65/207 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); catalogued as rs758154144; called by muse, mutect2, varscan2
- CNGA1 | c.1327del p.T443Qfs*8 | Frame Shift Del (DEL) | VAF 94/333 reads (28%) | catalogued as rs772867912; called by mutect2, pindel, varscan2
- CNGA4 | c.328G>A p.V110I | Missense Mutation (SNP) | VAF 104/367 reads (28%) | SIFT tolerated (0.91); PolyPhen benign (0.005); catalogued as rs774738730, COSV66005048; called by muse, mutect2, varscan2
- CNR1 | c.853G>A p.V285I | Missense Mutation (SNP) | VAF 127/338 reads (38%) | SIFT tolerated (0.61); PolyPhen benign (0.013); catalogued as rs199892728, COSV62990502; called by muse, mutect2, varscan2
- COL15A1 | c.2876T>C p.I959T | Missense Mutation (SNP) | VAF 132/391 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.058); catalogued as rs1037492928; called by muse, mutect2, varscan2
- COL24A1 | c.1682G>C p.G561A | Missense Mutation (SNP) | VAF 108/322 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762150921, COSV65302922; called by muse, mutect2, varscan2
- COL6A1 | c.2419G>A p.A807T | Missense Mutation (SNP) | VAF 53/211 reads (25%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs143925936; called by muse, mutect2, varscan2
- COL6A2 | c.2851G>A p.V951I | Missense Mutation (SNP) | VAF 137/394 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.12); catalogued as rs111630733, COSV99385235; called by muse, mutect2, varscan2
- COLGALT1 | c.1516G>A p.A506T | Missense Mutation (SNP) | VAF 153/549 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs368380442; called by muse, mutect2, varscan2
- COTL1 | c.287C>T p.T96M | Missense Mutation (SNP) | VAF 33/350 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749367597, COSV52289491, COSV52290276; called by muse, mutect2
- CPSF1 | c.1036G>A p.V346M | Missense Mutation (SNP) | VAF 179/494 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs922817063; called by muse, mutect2, varscan2
- CPXM2 | c.1002G>A p.M334I | Missense Mutation (SNP) | VAF 73/208 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.852); catalogued as COSV99580736; called by muse, mutect2, varscan2
- CRACDL | c.929C>T p.A310V | Missense Mutation (SNP) | VAF 163/473 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.117); catalogued as rs767555812; called by muse, mutect2, varscan2
- CRAT | c.495del p.K166Sfs*5 | Frame Shift Del (DEL) | VAF 118/365 reads (32%) | catalogued as rs772054700, COSV58879005; called by mutect2, pindel, varscan2
- CRCT1 | c.160G>A p.G54S | Missense Mutation (SNP) | VAF 193/516 reads (37%) | PolyPhen possibly damaging (0.796); catalogued as rs374162866, COSV57500797; called by muse, mutect2, varscan2
- CRKL | c.871G>A p.V291I | Missense Mutation (SNP) | VAF 118/387 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as rs1001709647, COSV62883193; called by muse, mutect2, varscan2
- CROCC2 | c.2291C>T p.A764V | Missense Mutation (SNP) | VAF 22/495 reads (4%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.455); catalogued as rs1219002261; called by muse, mutect2
- CROT | c.34C>T p.R12* | Nonsense Mutation (SNP) | VAF 63/238 reads (26%) | catalogued as rs140842977; called by muse, mutect2, varscan2
- CS | c.764C>T p.T255M | Missense Mutation (SNP) | VAF 109/300 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs964495854; called by muse, mutect2, varscan2
- CSF2RA | c.436dup p.R146Pfs*2 | Frame Shift Ins (INS) | VAF 175/531 reads (33%) | catalogued as rs1384224781; called by mutect2, pindel, varscan2
- CSMD3 | c.10920del p.F3640Lfs*61 (on ENST00000297405 / NM_001363185.1; = p.F3471Lfs*61 on NM_052900.3) | Frame Shift Del (DEL) | VAF 131/374 reads (35%) | catalogued as rs766438669; called by mutect2, pindel, varscan2
- CSMD3 | c.684G>A p.W228* | Nonsense Mutation (SNP) | VAF 102/500 reads (20%) | catalogued as COSV52165637, COSV52307532; called by muse, mutect2
- CSPG4 | c.839C>T p.A280V | Missense Mutation (SNP) | VAF 150/621 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.322); catalogued as rs772756930, COSV57894433; called by muse, mutect2, varscan2
- CSPG5 | c.1231C>T p.R411C | Missense Mutation (SNP) | VAF 144/408 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1246833442, COSV53129907; called by muse, mutect2, varscan2
- CTIF | c.1054C>T p.R352* | Nonsense Mutation (SNP) | VAF 112/311 reads (36%) | catalogued as rs748876705, COSV56487655; called by muse, mutect2, varscan2
- CUEDC1 | c.332del p.P111Rfs*136 | Frame Shift Del (DEL) | VAF 40/250 reads (16%) | catalogued as COSV100804649, COSV64227288; called by pindel, varscan2
- CWF19L2 | c.287del p.K96Rfs*41 | Frame Shift Del (DEL) | VAF 32/116 reads (28%) | catalogued as rs772257590; called by mutect2, varscan2
- CYFIP1 | c.1601G>A p.R534Q | Missense Mutation (SNP) | VAF 139/462 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.386); catalogued as rs1159299086; called by muse, mutect2, varscan2
- CYHR1 | c.563C>T p.A188V | Missense Mutation (SNP) | VAF 66/533 reads (12%) | SIFT tolerated (0.35); PolyPhen benign (0.113); catalogued as COSV71324651; called by muse, mutect2, varscan2
- CYP26C1 | c.496C>T p.R166W | Missense Mutation (SNP) | VAF 185/504 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV53323680; called by muse, mutect2, varscan2
- CYP46A1 | c.1444del p.V482Cfs*102 | Frame Shift Del (DEL) | VAF 139/467 reads (30%) | catalogued as COSV55894511; called by mutect2, pindel, varscan2
- CYP4F8 | c.1181del p.P394Qfs*85 | Frame Shift Del (DEL) | VAF 131/593 reads (22%) | catalogued as COSV57854931; called by mutect2, pindel, varscan2
- CYS1 | c.407C>T p.P136L | Missense Mutation (SNP) | VAF 138/404 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.247); catalogued as rs780173331, COSV100007622, COSV59940275; called by muse, mutect2, varscan2
- CYSLTR2 | c.718G>T p.V240F | Missense Mutation (SNP) | VAF 138/381 reads (36%) | SIFT tolerated (0.69); PolyPhen benign (0.188); catalogued as COSV56165813; called by muse, mutect2, varscan2
- DAB2IP | c.661G>A p.E221K (on ENST00000408936; = p.E193K on NM_032552.3) | Missense Mutation (SNP) | VAF 107/324 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52257289, COSV99406465; called by muse, mutect2, varscan2
- DAB2IP | c.1816G>A p.G606S (on ENST00000408936; = p.G578S on NM_032552.3) | Missense Mutation (SNP) | VAF 154/436 reads (35%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.998); catalogued as rs369754590; called by muse, mutect2, varscan2
- DACH1 | c.635C>A p.P212H | Missense Mutation (SNP) | VAF 156/419 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV57519819; called by muse, mutect2, varscan2
- DAXX | c.716T>C p.L239P | Missense Mutation (SNP) | VAF 213/569 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56468672; called by muse, mutect2, varscan2
- DCAF6 | c.1772G>A p.R591H (on ENST00000312263 / NM_001349778.1; = p.R611H on NM_018442.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 87/331 reads (26%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as rs759746198, COSV56576114; called by muse, mutect2, varscan2
- DCDC1 | c.4871T>G p.M1624R (on ENST00000597505 / NM_001367979.1; = p.M731R on NM_020869.3) | Missense Mutation (SNP) | VAF 92/282 reads (33%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.483); catalogued as COSV100360714; called by muse, varscan2
- DCTN1 | c.2754del p.S919Afs*25 | Frame Shift Del (DEL) | VAF 95/279 reads (34%) | catalogued as rs1229620804; called by mutect2, pindel, varscan2
- DDRGK1 | c.475G>A p.E159K | Missense Mutation (SNP) | VAF 98/311 reads (32%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); catalogued as rs780988105, COSV63226490; called by muse, mutect2, varscan2
- DDX54 | c.2081+1del p.X694_splice | Splice Site (DEL) | VAF 110/351 reads (31%) | catalogued as rs777863339; called by mutect2, pindel, varscan2
- DDX60 | c.119del p.L40* | Frame Shift Del (DEL) | VAF 45/140 reads (32%) | catalogued as rs763030135; called by mutect2, varscan2
- DEFB129 | c.333del p.F111Lfs*15 | Frame Shift Del (DEL) | VAF 116/375 reads (31%) | catalogued as rs765896284; called by mutect2, pindel, varscan2
- DENND3 | c.680C>T p.T227M | Missense Mutation (SNP) | VAF 133/592 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs767503171; called by muse, mutect2, varscan2
- DGKA | c.2176dup p.R726Pfs*79 | Frame Shift Ins (INS) | VAF 56/346 reads (16%) | catalogued as rs748318989; called by mutect2, varscan2
- DGKD | c.3034G>A p.A1012T (on ENST00000264057 / NM_152879.3; = p.A968T on NM_003648.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 141/384 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.149); catalogued as rs755394472, COSV99895455, COSV99896055; called by muse, mutect2, varscan2
- DHRS7B | c.133C>T p.R45C | Missense Mutation (SNP) | VAF 139/440 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs374791066; called by muse, mutect2, varscan2
- DHX9 | c.2290C>T p.R764* | Nonsense Mutation (SNP) | VAF 127/386 reads (33%) | catalogued as COSV62361116; called by muse, mutect2, varscan2
- DIPK1A | c.356C>T p.A119V | Missense Mutation (SNP) | VAF 78/264 reads (30%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as rs767266592, COSV100942006; called by muse, mutect2, varscan2
- DISP3 | c.1411A>T p.S471C | Missense Mutation (SNP) | VAF 135/331 reads (41%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.979); catalogued as COSV53825960; called by muse, mutect2, varscan2
- DISP3 | c.3805dup p.H1269Pfs*115 | Frame Shift Ins (INS) | VAF 92/298 reads (31%) | catalogued as rs756156984; called by mutect2, varscan2
- DKKL1 | c.170G>T p.R57L | Missense Mutation (SNP) | VAF 181/392 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV55562423; called by muse, mutect2
- DLEC1 | c.1240C>T p.P414S | Missense Mutation (SNP) | VAF 168/242 reads (69%) | SIFT tolerated (0.48); PolyPhen benign (0.058); catalogued as COSV57299351; called by muse, mutect2
- DNAH17 | c.12583_12585del p.E4195del | In Frame Del (DEL) | VAF 74/209 reads (35%) | catalogued as rs762690623; called by pindel, varscan2
- DNAH3 | c.8927del p.G2976Efs*20 | Frame Shift Del (DEL) | VAF 155/458 reads (34%) | catalogued as rs1567542268; called by mutect2, pindel, varscan2
- DNAH9 | c.349C>T p.R117C | Missense Mutation (SNP) | VAF 146/418 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as rs1473794952; called by mutect2, varscan2
- DNAJC18 | c.194C>T p.T65M | Missense Mutation (SNP) | VAF 144/366 reads (39%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.991); catalogued as rs371984025; called by muse, mutect2, varscan2
- DNAJC24 | c.8C>T p.A3V | Missense Mutation (SNP) | VAF 70/280 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.434); catalogued as rs1203225587, COSV60841824; called by muse, mutect2, varscan2
- DNAJC5 | c.473A>C p.Q158P | Missense Mutation (SNP) | VAF 84/246 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.014); catalogued as COSV62672879; called by muse, varscan2
- DNER | c.1766C>T p.P589L | Missense Mutation (SNP) | VAF 94/309 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59160709; called by muse, mutect2, varscan2
- DNHD1 | c.7669C>T p.R2557C | Missense Mutation (SNP) | VAF 124/392 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.376); catalogued as rs901692242; called by muse, mutect2, varscan2
- DNM2 | c.626T>C p.L209P | Missense Mutation (SNP) | VAF 111/473 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58969394; called by muse, mutect2, varscan2
- DOCK3 | c.5555del p.P1852Qfs*45 | Frame Shift Del (DEL) | VAF 54/158 reads (34%) | catalogued as rs782552436; called by mutect2, varscan2
- DSCC1 | c.1021C>A p.L341I | Missense Mutation (SNP) | VAF 40/434 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV58087957; called by muse, mutect2
- DSG3 | c.1709_1712del p.D570Vfs*12 | Frame Shift Del (DEL) | VAF 54/346 reads (16%) | catalogued as rs755731286; called by pindel, varscan2
- DST | c.13182del p.V4395Ffs*13 (on ENST00000361203 / NM_001374722.1; = p.V1983Ffs*13 on NM_015548.5) | Frame Shift Del (DEL) | VAF 70/226 reads (31%) | catalogued as rs1190969813; called by mutect2, pindel, varscan2
- DST | c.1021T>C p.W341R | Missense Mutation (SNP) | VAF 63/176 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55037350; called by muse, mutect2, varscan2
- DUS1L | c.557C>T p.S186L | Missense Mutation (SNP) | VAF 121/363 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.01); catalogued as rs780853019, COSV57647634; called by muse, mutect2, varscan2
- DYNC1H1 | c.483del p.F161Lfs*52 | Frame Shift Del (DEL) | VAF 93/258 reads (36%) | catalogued as rs1566996283; called by mutect2, pindel, varscan2
- DYNC1I2 | c.105del p.E36Kfs*34 | Frame Shift Del (DEL) | VAF 51/200 reads (26%) | catalogued as rs755197346; called by mutect2, varscan2
- DZIP1L | c.844G>A p.A282T | Missense Mutation (SNP) | VAF 30/140 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.06); catalogued as rs199809396, COSV100551543, COSV59521946; called by muse, mutect2, varscan2
- DZIP1L | c.392G>A p.R131H | Missense Mutation (SNP) | VAF 163/432 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); catalogued as rs978089953, COSV100551288; called by muse, mutect2, varscan2
- EBF2 | c.947T>C p.V316A | Missense Mutation (SNP) | VAF 50/325 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.943); catalogued as COSV101282256; called by muse, mutect2, varscan2
- EFCC1 | c.533G>A p.R178H | Missense Mutation (SNP) | VAF 36/622 reads (6%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.579); catalogued as rs1022674399; called by muse, mutect2
- EFR3A | c.43C>T p.R15C | Missense Mutation (SNP) | VAF 76/447 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs371388414; called by muse, varscan2
- EGFR | c.2320G>A p.V774M | Missense Mutation (SNP) | VAF 106/365 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs567477136, COSV51777313, COSV51843665; called by muse, mutect2
- EGFR | c.2795G>A p.R932H | Missense Mutation (SNP) | VAF 106/348 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51806557; called by muse, mutect2, varscan2
- EGLN1 | c.1031G>A p.R344Q | Missense Mutation (SNP) | VAF 31/335 reads (9%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.898); catalogued as COSV64147901; called by muse, mutect2
- EGR4 | c.301C>G p.R101G | Missense Mutation (SNP) | VAF 143/468 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.041); catalogued as COSV101474243; called by muse, mutect2, varscan2
- EML1 | c.972del p.F324Lfs*41 | Frame Shift Del (DEL) | VAF 76/360 reads (21%) | catalogued as COSV99214925; called by mutect2, pindel, varscan2
- EMX2 | c.398G>A p.R133H | Missense Mutation (SNP) | VAF 89/266 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1316096191, COSV71294538; called by muse, mutect2, varscan2
- ENDOU | c.539G>A p.R180H (on ENST00000422538 / NM_001172439.2; = p.R139H on NM_006025.4) | Missense Mutation (SNP) | VAF 105/315 reads (33%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as rs765301352, COSV57464832; called by muse, mutect2, varscan2
- ENPP7 | c.1102G>A p.A368T | Missense Mutation (SNP) | VAF 125/403 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs201643146; called by muse, mutect2, varscan2
- EOMES | c.995dup p.K333Qfs*11 | Frame Shift Ins (INS) | VAF 114/416 reads (27%) | catalogued as rs1309565164; called by pindel, varscan2
- EP300 | c.5528A>G p.Q1843R | Missense Mutation (SNP) | VAF 150/464 reads (32%) | SIFT tolerated (0.59); PolyPhen benign (0.328); catalogued as COSV54333876; called by muse, mutect2, varscan2
- EPHA6 | c.149C>A p.P50H | Missense Mutation (SNP) | VAF 173/513 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.305); catalogued as COSV67583620; called by muse, mutect2, varscan2
- EPHX3 | c.256C>T p.R86C | Missense Mutation (SNP) | VAF 77/401 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); catalogued as COSV54585966, COSV54592576; called by muse, mutect2, varscan2
- ERAP2 | c.2009T>C p.V670A | Missense Mutation (SNP) | VAF 46/222 reads (21%) | SIFT tolerated (0.3); PolyPhen benign (0.086); catalogued as rs746597629, COSV101163517; called by muse, mutect2, varscan2
- ERBB4 | c.3193G>A p.V1065I | Missense Mutation (SNP) | VAF 90/236 reads (38%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs149665378; called by muse, mutect2, varscan2
- ERVMER34-1 | c.899del p.L300Cfs*33 | Frame Shift Del (DEL) | VAF 120/353 reads (34%) | catalogued as rs779855268; called by mutect2, varscan2
- ERVV-2 | c.788del p.N263Ifs*11 | Frame Shift Del (DEL) | VAF 18/46 reads (39%) | catalogued as rs1462590370; called by mutect2, varscan2
- ESF1 | c.512dup p.N171Kfs*24 | Frame Shift Ins (INS) | VAF 48/200 reads (24%) | catalogued as rs745713173; called by mutect2, varscan2
- ESPN | c.2225C>T p.T742M | Missense Mutation (SNP) | VAF 157/474 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as rs754878916, COSV99060708; called by muse, mutect2, varscan2
- ESRP1 | c.523C>T p.R175* | Nonsense Mutation (SNP) | VAF 92/322 reads (29%) | catalogued as COSV64408100; called by muse, mutect2, varscan2
- EVA1B | c.64C>T p.R22C | Missense Mutation (SNP) | VAF 98/292 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.872); catalogued as COSV54634201, COSV54634877, COSV99584108; called by muse, mutect2, varscan2
- EVPL | c.518C>T p.A173V | Missense Mutation (SNP) | VAF 34/348 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.158); catalogued as COSV56914261; called by muse, mutect2
- EVX2 | c.527C>T p.A176V | Missense Mutation (SNP) | VAF 208/569 reads (37%) | SIFT tolerated (0.2); PolyPhen benign (0.011); catalogued as COSV99079562; called by muse, mutect2, varscan2
- EXOC7 | c.73_74del p.L25Vfs*15 | Frame Shift Del (DEL) | VAF 72/294 reads (24%) | catalogued as rs772123087; called by pindel, varscan2
- EYS | c.2854del p.C952Vfs*16 | Frame Shift Del (DEL) | VAF 33/150 reads (22%) | catalogued as rs779877426; called by mutect2, pindel, varscan2
- F7 | c.883G>A p.V295I | Missense Mutation (SNP) | VAF 178/501 reads (36%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as rs959914744; called by muse, mutect2, varscan2
- FAAH | c.1076C>T p.T359M | Missense Mutation (SNP) | VAF 108/307 reads (35%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.826); catalogued as rs200807011; called by muse, mutect2, varscan2
- FAM187A | c.1066C>T p.R356W | Missense Mutation (SNP) | VAF 113/305 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.017); catalogued as rs1453848416; called by muse, mutect2, varscan2
- FAM189A1 | c.1465G>A p.A489T | Missense Mutation (SNP) | VAF 145/467 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1321041298, COSV54271469; called by muse, mutect2, varscan2
- FAM25C | c.64G>A p.E22K | Missense Mutation (SNP) | VAF 105/627 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.057); catalogued as rs80266306; called by muse, mutect2, varscan2
- FAM53B | c.770C>T p.A257V | Missense Mutation (SNP) | VAF 51/407 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs572365285; called by muse, mutect2, varscan2
- FAM98A | c.522del p.K174Nfs*2 | Frame Shift Del (DEL) | VAF 48/135 reads (36%) | catalogued as rs1237814873; called by mutect2, varscan2
- FARS2 | c.701A>G p.E234G | Missense Mutation (SNP) | VAF 122/365 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1009933151; called by muse, varscan2
- FASTKD2 | c.1706T>C p.L569P | Missense Mutation (SNP) | VAF 27/413 reads (7%) | SIFT tolerated (0.24); PolyPhen benign (0.2); catalogued as rs1161942794; called by muse, mutect2
- FAT1 | c.5518A>G p.T1840A | Missense Mutation (SNP) | VAF 15/389 reads (4%) | SIFT tolerated (0.51); PolyPhen benign (0.015); catalogued as rs1384682548; called by muse, mutect2
- FAT3 | c.1408C>T p.P470S | Missense Mutation (SNP) | VAF 109/316 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1182457058; called by muse, mutect2, varscan2
- FBLN2 | c.2537G>A p.G846D | Missense Mutation (SNP) | VAF 107/334 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776478547; called by muse, mutect2, varscan2
- FBN1 | c.2833G>A p.A945T | Missense Mutation (SNP) | VAF 82/252 reads (33%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as CD145748; called by muse, mutect2, varscan2
- FBXL19 | c.614del p.P205Rfs*26 | Frame Shift Del (DEL) | VAF 120/330 reads (36%) | catalogued as rs745385709; called by mutect2, varscan2
- FBXO11 | c.509A>G p.Y170C (on ENST00000403359 / NM_001190274.2; = p.Y86C on NM_025133.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/287 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.683); catalogued as rs768167573; called by muse, mutect2, varscan2
- FBXO31 | c.1300G>A p.A434T | Missense Mutation (SNP) | VAF 20/561 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.058); catalogued as COSV100291403; called by muse, mutect2
- FCHSD1 | c.7C>A p.P3T | Missense Mutation (SNP) | VAF 124/379 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as rs772677708; called by muse, mutect2, varscan2
- FCN2 | c.692C>T p.A231V | Missense Mutation (SNP) | VAF 69/211 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.939); catalogued as rs199687442, COSV52475726, COSV52479112, COSV99391425; called by muse, mutect2, varscan2
- FER1L6 | c.3708del p.G1237Afs*10 | Frame Shift Del (DEL) | VAF 260/454 reads (57%) | catalogued as rs747094222, COSV67548414; called by mutect2, varscan2
- FERMT3 | c.616G>A p.D206N | Missense Mutation (SNP) | VAF 45/554 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.056); catalogued as rs201973872, COSV54183443; called by muse, mutect2
- FGD3 | c.448G>A p.A150T | Missense Mutation (SNP) | VAF 130/367 reads (35%) | SIFT tolerated (0.59); PolyPhen benign (0.009); catalogued as COSV61598660; called by muse, mutect2, varscan2
- FGF2 | c.17del p.G6Vfs*4 | Frame Shift Del (DEL) | VAF 80/228 reads (35%) | catalogued as rs776164719; called by mutect2, varscan2
- FHOD3 | c.1005del p.S336Vfs*138 | Frame Shift Del (DEL) | VAF 135/437 reads (31%) | catalogued as rs777980924; called by mutect2, pindel, varscan2
- FIGNL1 | c.372del p.K124Nfs*15 | Frame Shift Del (DEL) | VAF 74/269 reads (28%) | catalogued as COSV63554218; called by mutect2, pindel, varscan2
- FKBP10 | c.21dup p.S8Qfs*67 | Frame Shift Ins (INS) | VAF 105/311 reads (34%) | catalogued as rs782271121; called by mutect2, varscan2
- FLOT2 | c.403C>T p.R135W | Missense Mutation (SNP) | VAF 104/353 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs759768535, COSV101204735; called by muse, mutect2, varscan2
- FLT3 | c.2317del p.R773Gfs*8 | Frame Shift Del (DEL) | VAF 68/278 reads (24%) | catalogued as rs1566063342; called by mutect2, varscan2
- FMNL3 | c.1782_1784del p.D594del | In Frame Del (DEL) | VAF 81/256 reads (32%) | catalogued as rs759178341; called by pindel, varscan2
- FMO1 | c.1262G>A p.G421D | Missense Mutation (SNP) | VAF 54/160 reads (34%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.969); catalogued as COSV100708042; called by muse, mutect2, varscan2
- FOXN3 | c.1338del p.E447Rfs*7 (on ENST00000261302; = p.E425Rfs*7 on NM_005197.4) | Frame Shift Del (DEL) | VAF 125/395 reads (32%) | catalogued as rs1566917904, COSV54312941; called by mutect2, pindel, varscan2
- FOXP4 | c.1429C>T p.R477C (on ENST00000307972 / NM_001012426.1; = p.R464C on NM_138457.3) | Missense Mutation (SNP) | VAF 53/298 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs778609898; called by muse, mutect2, varscan2
- FRA10AC1 | c.694del p.R232Efs*96 | Frame Shift Del (DEL) | VAF 42/142 reads (30%) | catalogued as rs775948504; called by mutect2, varscan2
- FRAS1 | c.6376C>T p.R2126C | Missense Mutation (SNP) | VAF 111/333 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.634); catalogued as rs779986441; called by muse, mutect2, varscan2
- FRMD1 | c.439G>A p.V147M | Missense Mutation (SNP) | VAF 109/372 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs151107075, COSV51960187; called by muse, mutect2, varscan2
- FRMPD2 | c.640C>T p.R214C | Missense Mutation (SNP) | VAF 150/449 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as rs199914001; called by muse, mutect2, varscan2
- FSIP2 | c.8191C>T p.P2731S | Missense Mutation (SNP) | VAF 110/341 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs1468617442, COSV58095448; called by muse, mutect2, varscan2
- FXR1 | c.419C>T p.A140V | Missense Mutation (SNP) | VAF 52/155 reads (34%) | SIFT tolerated (0.49); PolyPhen benign (0.05); catalogued as rs775084355; called by muse, varscan2
- GAL3ST3 | c.809G>A p.R270H | Missense Mutation (SNP) | VAF 141/301 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61749413; called by muse, mutect2, varscan2
- GAL3ST4 | c.713del p.P238Hfs*85 | Frame Shift Del (DEL) | VAF 154/480 reads (32%) | catalogued as rs1332058293; called by mutect2, pindel, varscan2
- GALK2 | c.752C>T p.A251V | Missense Mutation (SNP) | VAF 75/223 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.576); catalogued as rs199727284; called by muse, mutect2, varscan2
- GALNT9 | c.662G>A p.R221Q | Missense Mutation (SNP) | VAF 141/443 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.43); catalogued as rs368118153; called by muse, mutect2, varscan2
- GAS2L1 | c.1839dup p.P614Afs*13 | Frame Shift Ins (INS) | VAF 144/439 reads (33%) | catalogued as rs78929040; called by mutect2, varscan2
- GAS7 | c.627G>T p.K209N (on ENST00000432992 / NM_201433.2; = p.K69N on NM_003644.3) | Missense Mutation (SNP) | VAF 93/279 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.015); catalogued as COSV60436690; called by muse, mutect2, varscan2
- GFPT1 | c.902C>T p.A301V (on ENST00000357308 / NM_001244710.2; = p.A283V on NM_002056.4) | Missense Mutation (SNP) | VAF 96/336 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as rs372840289; called by muse, varscan2
- GGACT | c.91C>T p.R31W | Missense Mutation (SNP) | VAF 123/444 reads (28%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.804); catalogued as rs1356818703; called by muse, mutect2, varscan2
- GGT7 | c.1613G>A p.R538Q | Missense Mutation (SNP) | VAF 125/416 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.083); catalogued as rs1167884227; called by muse, mutect2, varscan2
- GHR | c.784G>T p.D262Y | Missense Mutation (SNP) | VAF 58/162 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as CS004347, CS130864; called by mutect2, varscan2
- GIPC1 | c.149del p.P50Lfs*48 | Frame Shift Del (DEL) | VAF 80/540 reads (15%) | catalogued as rs771881138; called by mutect2, varscan2
- GLO1 | c.368G>A p.R123Q | Missense Mutation (SNP) | VAF 96/256 reads (38%) | SIFT tolerated (0.27); PolyPhen benign (0.191); catalogued as rs376095398; called by muse, mutect2, varscan2
- GLYR1 | c.1140del p.R381Afs*20 | Frame Shift Del (DEL) | VAF 74/238 reads (31%) | catalogued as rs749150409; called by mutect2, varscan2
- GNG12 | c.202del p.T68Lfs*22 | Frame Shift Del (DEL) | VAF 60/228 reads (26%) | catalogued as rs1022402829; called by mutect2, pindel, varscan2
- GOLGA2 | c.2933G>A p.R978Q | Missense Mutation (SNP) | VAF 93/276 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.194); catalogued as rs756317048; called by muse, mutect2, varscan2
- GOT1 | c.125G>A p.R42H | Missense Mutation (SNP) | VAF 58/234 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65147002; called by muse, mutect2, varscan2
- GPC5 | c.835C>T p.R279* | Nonsense Mutation (SNP) | VAF 120/368 reads (33%) | catalogued as rs184809659, COSV65610669; called by muse, mutect2, varscan2
- GPR149 | c.469G>A p.V157M | Missense Mutation (SNP) | VAF 151/525 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.592); catalogued as rs768296181, COSV101078649; called by muse, mutect2, varscan2
- GPSM1 | c.1593del p.T532Pfs*11 | Frame Shift Del (DEL) | VAF 124/409 reads (30%) | catalogued as rs1211947280; called by mutect2, pindel, varscan2
- GRAMD4 | c.805G>A p.A269T | Missense Mutation (SNP) | VAF 65/216 reads (30%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.787); catalogued as rs747893794; called by muse, mutect2, varscan2
- GRB14 | c.1303C>T p.R435W | Missense Mutation (SNP) | VAF 71/235 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.59); catalogued as rs776488093, COSV55745224; called by muse, mutect2, varscan2
- GRIN3B | c.508G>A p.A170T | Missense Mutation (SNP) | VAF 307/621 reads (49%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as rs772290501; called by muse, mutect2, varscan2
- GRK2 | c.1230C>T p.A410= | Splice Region (SNP) | VAF 96/309 reads (31%) | catalogued as rs1381279717, COSV57952526; called by muse, mutect2, varscan2
- GRK5 | c.592G>A p.G198R | Missense Mutation (SNP) | VAF 79/300 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1345851560, COSV64865945; called by muse, mutect2, varscan2
- GRXCR1 | c.718C>T p.P240S | Missense Mutation (SNP) | VAF 97/274 reads (35%) | SIFT tolerated (0.76); PolyPhen benign (0.027); catalogued as rs756762124, COSV67670958, COSV67675681; called by muse, mutect2, varscan2
- GSE1 | c.1598del p.P533Rfs*38 | Frame Shift Del (DEL) | VAF 142/456 reads (31%) | catalogued as rs1374121803; called by pindel, varscan2
- GTF2F1 | c.1427del p.K476Sfs*9 | Frame Shift Del (DEL) | VAF 259/616 reads (42%) | catalogued as COSV55532171; called by mutect2, pindel, varscan2
- GTPBP10 | c.926dup p.N309Kfs*37 | Frame Shift Ins (INS) | VAF 36/132 reads (27%) | catalogued as rs745885335; called by mutect2, varscan2
- GUCY1A2 | c.383A>C p.K128T | Missense Mutation (SNP) | VAF 66/241 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.596); catalogued as COSV56502436, COSV56503210; called by muse, mutect2, varscan2
- GYG2 | c.954dup p.P319Afs*14 | Frame Shift Ins (INS) | VAF 113/166 reads (68%) | catalogued as rs770047512; called by mutect2, varscan2
- H1-5 | c.169C>T p.R57C | Missense Mutation (SNP) | VAF 20/450 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); catalogued as rs1251654170, COSV58900798; called by muse, mutect2
- H2AC6 | c.332A>G p.N111S | Missense Mutation (SNP) | VAF 90/275 reads (33%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.009); catalogued as rs1320219622; called by muse, mutect2, varscan2
- H2BC4 | c.182G>A p.G61D | Missense Mutation (SNP) | VAF 91/290 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.119); catalogued as COSV100020065, COSV58415545; called by muse, mutect2, varscan2
- HAND2 | c.247del p.V83Cfs*16 | Frame Shift Del (DEL) | VAF 270/403 reads (67%) | catalogued as CM105646; called by mutect2, varscan2
- HAPLN4 | c.970G>T p.A324S | Missense Mutation (SNP) | VAF 225/838 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.657); catalogued as COSV52271614; called by muse, mutect2, varscan2
- HDGF | c.623G>A p.R208Q | Missense Mutation (SNP) | VAF 150/435 reads (34%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0); catalogued as rs201482955; called by muse, mutect2, varscan2
- HDGFL2 | c.677del p.K226Rfs*45 | Frame Shift Del (DEL) | VAF 208/399 reads (52%) | catalogued as rs1219916331, COSV56682191; called by mutect2, varscan2
- HDHD3 | c.440del p.G147Afs*12 | Frame Shift Del (DEL) | VAF 142/424 reads (33%) | catalogued as rs763890764; called by mutect2, varscan2
- HEATR6 | c.3257C>T p.S1086L | Missense Mutation (SNP) | VAF 145/461 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.089); catalogued as rs533357378, COSV99482490; called by muse, mutect2, varscan2
- HEPACAM2 | c.554del p.N185Mfs*25 (on ENST00000394468 / NM_001039372.4; = p.N173Mfs*25 on NM_198151.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 140/503 reads (28%) | catalogued as COSV59062549; called by mutect2, pindel, varscan2
- HEXIM2 | c.140C>T p.P47L | Missense Mutation (SNP) | VAF 15/438 reads (3%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.031); catalogued as COSV56236535; called by muse, mutect2
- HNRNPA3 | c.718G>A p.G240S | Missense Mutation (SNP) | VAF 84/293 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.688); catalogued as COSV101182803; called by muse, mutect2, varscan2
- HNRNPCL2 | c.502G>A p.G168R | Missense Mutation (SNP) | VAF 116/428 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.897); catalogued as rs536039326; called by muse, mutect2, varscan2
- HOOK2 | c.230G>A p.R77Q | Missense Mutation (SNP) | VAF 165/337 reads (49%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs771858249, COSV53402190; called by muse, mutect2, varscan2
- HOXA3 | c.1144C>A p.L382I | Missense Mutation (SNP) | VAF 380/703 reads (54%) | SIFT tolerated (0.23); PolyPhen benign (0.011); catalogued as rs762935434; called by muse, mutect2, varscan2
- HPCAL1 | c.157G>A p.A53T | Missense Mutation (SNP) | VAF 92/292 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0.082); catalogued as rs375884714; called by muse, mutect2, varscan2
- HRNR | c.8428T>C p.Y2810H | Missense Mutation (SNP) | VAF 82/406 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.081); catalogued as rs767685767; called by muse, mutect2
- HSPG2 | c.13163C>T p.P4388L | Missense Mutation (SNP) | VAF 114/314 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs774279128; called by muse, varscan2
- HTR3E | c.919del p.L307Sfs*12 (on ENST00000415389 / NM_001256613.1; = p.L322Sfs*12 on NM_182589.2) | Frame Shift Del (DEL) | VAF 68/222 reads (31%) | catalogued as rs754509192; called by mutect2, varscan2
- HTR3E | c.1022del p.P341Hfs*42 (on ENST00000415389 / NM_001256613.1; = p.P356Hfs*42 on NM_182589.2) | Frame Shift Del (DEL) | VAF 152/426 reads (36%) | catalogued as COSV58948373; called by mutect2, varscan2
- HTRA1 | c.958G>A p.D320N | Missense Mutation (SNP) | VAF 90/268 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs376449340; called by muse, mutect2, varscan2
- HUS1 | c.341del p.T114Rfs*16 | Frame Shift Del (DEL) | VAF 65/265 reads (25%) | catalogued as COSV51840068; called by mutect2, pindel, varscan2
- HYDIN | c.1148G>A p.R383Q | Missense Mutation (SNP) | VAF 124/533 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs751449282, COSV55486197; called by muse, mutect2, varscan2
- IBA57 | c.832C>T p.R278C | Missense Mutation (SNP) | VAF 147/439 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763778871, COSV64511193; called by muse, mutect2, varscan2
- IDE | c.673A>G p.T225A | Missense Mutation (SNP) | VAF 68/199 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs961874330; called by muse, mutect2, varscan2
- IFI16 | c.12del p.K4Nfs*8 | Frame Shift Del (DEL) | VAF 14/93 reads (15%) | catalogued as rs1272199515; called by mutect2, pindel, varscan2
- IFIT1 | c.1007del p.K336Sfs*9 | Frame Shift Del (DEL) | VAF 75/267 reads (28%) | catalogued as rs1202143274; called by mutect2, pindel, varscan2
- IGHV4-34 | c.229A>G p.I77V | Missense Mutation (SNP) | VAF 49/289 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.075); catalogued as rs587670517; called by muse, mutect2, varscan2
- IGKV1D-42 | c.222A>C p.K74N | Missense Mutation (SNP) | VAF 99/345 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs752306072; called by muse, mutect2, varscan2
- IGSF9B | c.2362C>T p.R788C | Missense Mutation (SNP) | VAF 88/308 reads (29%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.818); catalogued as rs376908469; called by muse, mutect2, varscan2
- IKZF4 | c.1183C>T p.L395F | Missense Mutation (SNP) | VAF 147/381 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as rs760301697; called by muse, mutect2, varscan2
- IL2RA | c.181G>A p.G61R | Missense Mutation (SNP) | VAF 130/382 reads (34%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as rs201617475; called by muse, mutect2, varscan2
- IL6ST | c.1587del p.V530* | Frame Shift Del (DEL) | VAF 62/210 reads (30%) | catalogued as rs776023104; called by mutect2, varscan2
- IMPDH1 | c.1138G>A p.A380T (on ENST00000470772 / NM_001142573.2; = p.A466T on NM_000883.4) | Missense Mutation (SNP) | VAF 98/314 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs1216853795; called by muse, varscan2
- INKA2 | c.809G>A p.R270Q | Missense Mutation (SNP) | VAF 117/405 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs763243478, COSV100615923; called by muse, mutect2, varscan2
- INO80B | c.1035del p.E347Rfs*? | Frame Shift Del (DEL) | VAF 123/445 reads (28%) | catalogued as rs752165206; called by mutect2, pindel, varscan2
- INPP5F | c.2488_2490del p.S830del | In Frame Del (DEL) | VAF 86/259 reads (33%) | catalogued as rs752816097; called by pindel, varscan2
- INSYN2B | c.1169T>G p.L390R | Missense Mutation (SNP) | VAF 137/401 reads (34%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV56989492; called by muse, mutect2, varscan2
- INTS12 | c.41del p.L14* | Frame Shift Del (DEL) | VAF 72/254 reads (28%) | catalogued as COSV60863912; called by mutect2, varscan2
- INTU | c.395del p.N132Ifs*11 | Frame Shift Del (DEL) | VAF 78/222 reads (35%) | catalogued as rs771175764; called by mutect2, varscan2
- IPMK | c.983del p.K328Sfs*8 | Frame Shift Del (DEL) | VAF 102/349 reads (29%) | catalogued as COSV100880320; called by mutect2, pindel, varscan2
- IQCJ-SCHIP1 | c.425dup p.S143Qfs*12 (on ENST00000485419 / NM_001197113.1; = p.S67Qfs*12 on NM_014575.3) | Frame Shift Ins (INS) | VAF 118/360 reads (33%) | catalogued as rs750276127; called by mutect2, varscan2
- IQSEC3 | c.3521A>G p.Y1174C | Missense Mutation (SNP) | VAF 92/282 reads (33%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as rs1277816077; called by muse, mutect2, varscan2
- IRF2BPL | c.731del p.G244Vfs*101 | Frame Shift Del (DEL) | VAF 130/438 reads (30%) | catalogued as rs1356336393, COSV99468389; called by mutect2, pindel, varscan2
- IRF6 | c.298A>G p.T100A | Missense Mutation (SNP) | VAF 125/390 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); catalogued as HM030010; called by muse, mutect2, varscan2
- IRS2 | c.1168del p.L390* | Frame Shift Del (DEL) | VAF 41/162 reads (25%) | catalogued as rs1472715822; called by mutect2, pindel, varscan2
- IRX1 | c.1189C>G p.P397A | Missense Mutation (SNP) | VAF 107/385 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.107); catalogued as COSV57359974; called by muse, mutect2, varscan2
- ITPR2 | c.2573del p.N858Ifs*3 | Frame Shift Del (DEL) | VAF 20/160 reads (13%) | catalogued as rs1565669456; called by mutect2, pindel, varscan2
- ITPRIP | c.1394T>C p.L465P | Missense Mutation (SNP) | VAF 126/390 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs200915089; called by muse, mutect2, varscan2
- JAKMIP3 | c.172C>T p.R58W | Missense Mutation (SNP) | VAF 103/289 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as rs750533811, COSV53821355, COSV53828622; called by muse, mutect2, varscan2
- JCAD | c.3256G>A p.A1086T | Missense Mutation (SNP) | VAF 155/438 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs779099402; called by muse, mutect2, varscan2
- JCAD | c.1515dup p.G506Rfs*23 | Frame Shift Ins (INS) | VAF 148/408 reads (36%) | catalogued as rs770240166; called by mutect2, varscan2
- KANK4 | c.467G>A p.R156Q | Missense Mutation (SNP) | VAF 146/427 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs781772189, COSV100587529; called by muse, mutect2, varscan2
- KARS1 | c.77G>A p.R26H | Missense Mutation (SNP) | VAF 83/266 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as rs779473612, COSV100093723; called by muse, mutect2, varscan2
- KAT7 | c.46G>A p.E16K | Missense Mutation (SNP) | VAF 123/312 reads (39%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.353); catalogued as rs1407775609; called by muse, mutect2, varscan2
- KATNAL1 | c.1253C>T p.A418V | Missense Mutation (SNP) | VAF 63/304 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as rs1351550890, COSV66062875; called by muse, mutect2, varscan2
- KCND1 | c.319C>T p.R107W | Missense Mutation (SNP) | VAF 184/253 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs782678377, COSV104373769; called by muse, mutect2, varscan2
- KCNJ14 | c.493G>A p.A165T | Missense Mutation (SNP) | VAF 165/677 reads (24%) | SIFT tolerated (0.34); PolyPhen benign (0.031); catalogued as rs1238345127; called by muse, mutect2, varscan2
- KCNJ3 | c.316G>A p.A106T | Missense Mutation (SNP) | VAF 117/424 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99716335; called by muse, mutect2, varscan2
- KCNK7 | c.853G>T p.G285W | Missense Mutation (SNP) | VAF 125/372 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as COSV100442252, COSV100442390; called by muse, mutect2, varscan2
- KCNV1 | c.1484del p.G495Efs*20 | Frame Shift Del (DEL) | VAF 82/371 reads (22%) | catalogued as COSV52088986; called by mutect2, varscan2
- KCP | c.119C>T p.A40V | Missense Mutation (SNP) | VAF 129/443 reads (29%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as rs1258977482; called by muse, mutect2, varscan2
- KDM2A | c.2213G>T p.R738L | Missense Mutation (SNP) | VAF 126/417 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.326); catalogued as COSV100445519; called by muse, mutect2, varscan2
- KDM3A | c.344C>T p.T115M | Missense Mutation (SNP) | VAF 74/221 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs772689138; called by muse, mutect2, varscan2
- KIAA0586 | c.1927A>G p.T643A (on ENST00000619416 / NM_001244190.2; = p.T582A on NM_014749.5) | Missense Mutation (SNP) | VAF 62/344 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1365055691; called by muse, mutect2
- KIAA1109 | c.10556G>A p.R3519Q | Missense Mutation (SNP) | VAF 55/183 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs377565919; called by muse, mutect2, varscan2
- KIF14 | c.2986del p.M996Cfs*4 | Frame Shift Del (DEL) | VAF 53/219 reads (24%) | catalogued as rs1164624349; called by mutect2, pindel, varscan2
- KIF18A | c.2395C>T p.R799W | Missense Mutation (SNP) | VAF 47/158 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs193161481, COSV54180754; called by muse, mutect2, varscan2
- KIF26A | c.1879C>T p.R627C | Missense Mutation (SNP) | VAF 142/455 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752612776; called by muse, mutect2
- KLHDC7B | c.488del p.G163Afs*83 (on ENST00000395676; = p.G804Afs*83 on NM_138433.5) | Frame Shift Del (DEL) | VAF 167/520 reads (32%) | catalogued as rs1435543889; called by mutect2, pindel, varscan2
- KLHL26 | c.800C>T p.T267M | Missense Mutation (SNP) | VAF 36/651 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.528); catalogued as rs765271368; called by muse, mutect2
- KLK2 | c.500G>A p.R167H | Missense Mutation (SNP) | VAF 87/348 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.009); catalogued as rs142858357; called by muse, mutect2, varscan2
- KMT2A | c.6542C>T p.P2181L | Missense Mutation (SNP) | VAF 108/347 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.922); catalogued as rs1555045986, COSV100629336, COSV63290564; called by muse, mutect2, varscan2
- KMT2B | c.3712C>T p.P1238S | Missense Mutation (SNP) | VAF 117/499 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.438); catalogued as rs1259921278; called by muse, mutect2, varscan2
- KMT2B | c.6160G>T p.G2054* | Nonsense Mutation (SNP) | VAF 349/670 reads (52%) | catalogued as COSV55870958; called by muse, mutect2, varscan2
- KMT5A | c.931G>A p.D311N | Missense Mutation (SNP) | VAF 110/392 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0.017); catalogued as rs757525592, COSV57863993; called by muse, varscan2
- KRT17 | c.739G>A p.V247M | Missense Mutation (SNP) | VAF 110/336 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.473); catalogued as rs141092585; called by muse, varscan2
- KRTAP10-1 | c.34G>A p.A12T | Missense Mutation (SNP) | VAF 56/372 reads (15%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs782420165; called by muse, mutect2, varscan2
- L3MBTL2 | c.1231G>A p.V411I | Missense Mutation (SNP) | VAF 117/377 reads (31%) | SIFT tolerated (0.22); PolyPhen benign (0.115); catalogued as rs141102760; called by muse, mutect2, varscan2
- L3MBTL4 | c.1597G>A p.A533T | Missense Mutation (SNP) | VAF 116/309 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.824); catalogued as rs1477679571; called by muse, mutect2, varscan2
- LAMA2 | c.1757C>T p.A586V | Missense Mutation (SNP) | VAF 88/283 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs373005444; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LAMA5 | c.3683C>T p.P1228L | Missense Mutation (SNP) | VAF 119/373 reads (32%) | SIFT tolerated (0.38); PolyPhen benign (0.007); catalogued as rs200189344; called by muse, mutect2, varscan2
- LAMC1 | c.2607dup p.G870Wfs*30 | Frame Shift Ins (INS) | VAF 98/305 reads (32%) | catalogued as rs775483679; called by mutect2, pindel, varscan2
- LARGE1 | c.232G>A p.A78T | Missense Mutation (SNP) | VAF 85/466 reads (18%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.11); catalogued as rs771323307; called by muse, mutect2, varscan2
- LARP7 | c.77del p.K26Rfs*36 | Frame Shift Del (DEL) | VAF 93/310 reads (30%) | catalogued as rs781724052; called by mutect2, pindel, varscan2
- LATS2 | c.1163C>T p.A388V | Missense Mutation (SNP) | VAF 163/745 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0.006); catalogued as rs12867400; called by muse, mutect2, varscan2
- LBX1 | c.199G>A p.A67T | Missense Mutation (SNP) | VAF 192/518 reads (37%) | SIFT tolerated (0.25); PolyPhen benign (0.033); catalogued as rs1433372909; called by muse, mutect2, varscan2
- LCT | c.5381C>T p.A1794V | Missense Mutation (SNP) | VAF 76/252 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as rs183725992; called by muse, mutect2, varscan2
- LILRA2 | c.515C>T p.A172V | Missense Mutation (SNP) | VAF 107/902 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs148910186; called by muse, varscan2
- LNPEP | c.434del p.N145Tfs*6 | Frame Shift Del (DEL) | VAF 106/366 reads (29%) | catalogued as rs748712732; called by mutect2, varscan2
- LRCH3 | c.352C>T p.R118C | Missense Mutation (SNP) | VAF 78/234 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1278141413, COSV58392614; called by muse, mutect2, varscan2
- LRFN2 | c.1852G>A p.A618T | Missense Mutation (SNP) | VAF 51/516 reads (10%) | SIFT tolerated (0.57); PolyPhen benign (0.006); catalogued as rs61745019, COSV57829194; called by muse, mutect2
- LRP1 | c.4267C>T p.R1423C | Missense Mutation (SNP) | VAF 23/568 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV54520303; called by muse, mutect2
- LRP1 | c.5173A>G p.S1725G | Missense Mutation (SNP) | VAF 117/387 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.058); catalogued as COSV54527944; called by muse, mutect2, varscan2
- LRP2 | c.572G>A p.G191D | Missense Mutation (SNP) | VAF 57/328 reads (17%) | SIFT tolerated (0.66); PolyPhen benign (0.015); catalogued as COSV55574465; called by muse, mutect2, varscan2
- LRP6 | c.1277G>A p.R426Q | Missense Mutation (SNP) | VAF 165/456 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as rs1187307515, COSV99743000; called by muse, mutect2, varscan2
- LRRC10B | c.446G>A p.R149H | Missense Mutation (SNP) | VAF 135/400 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.893); catalogued as rs1007219991; called by muse, mutect2, varscan2
- LRRC3 | c.53A>G p.E18G | Missense Mutation (SNP) | VAF 11/373 reads (3%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs1215184049; called by muse, mutect2
- LRRC8C | c.1524del p.W509Gfs*13 | Frame Shift Del (DEL) | VAF 45/268 reads (17%) | catalogued as rs762972819; called by mutect2, pindel, varscan2
- LRRK2 | c.4235G>A p.R1412Q | Missense Mutation (SNP) | VAF 71/232 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.607); catalogued as rs751263185, COSV100110924, COSV54174411; called by muse, mutect2, varscan2
- LSG1 | c.475C>T p.R159* | Nonsense Mutation (SNP) | VAF 93/273 reads (34%) | catalogued as rs561924888; called by muse, mutect2, varscan2
- LY6G6E | c.140G>A p.R47Q | Missense Mutation (SNP) | VAF 129/370 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs1483862958; called by muse, mutect2, varscan2
- LYPD3 | c.598A>G p.T200A | Missense Mutation (SNP) | VAF 38/518 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as rs760026685, COSV54988194; called by muse, mutect2
- LYST | c.1897A>T p.K633* | Nonsense Mutation (SNP) | VAF 49/280 reads (18%) | catalogued as rs747022808, CM1410821, COSV67708193; called by muse, mutect2, varscan2
- LZTS2 | c.1267G>A p.A423T | Missense Mutation (SNP) | VAF 128/383 reads (33%) | SIFT tolerated (0.3); PolyPhen benign (0.177); catalogued as rs369124299; called by muse, mutect2, varscan2
- MACF1 | c.12602G>A p.R4201Q (on ENST00000372915; = p.R2134Q on NM_012090.5) | Missense Mutation (SNP) | VAF 110/395 reads (28%) | catalogued as rs377759390; called by muse, mutect2, varscan2
- MACF1 | c.21100C>T p.R7034C (on ENST00000372915; = p.R5079C on NM_012090.5) | Missense Mutation (SNP) | VAF 108/339 reads (32%) | catalogued as rs747182535, COSV57108915; called by muse, mutect2, varscan2
- MACROD2 | c.355A>G p.N119D | Missense Mutation (SNP) | VAF 124/336 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.215); catalogued as COSV53960490; called by muse, mutect2, varscan2
- MAN1B1 | c.1216C>T p.R406W | Missense Mutation (SNP) | VAF 66/367 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.833); catalogued as rs1037141680; called by muse, mutect2, varscan2
- MAP2 | c.4412C>T p.A1471V | Missense Mutation (SNP) | VAF 27/226 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.089); catalogued as rs1255997387; called by muse, varscan2
- MAP4 | c.2755del p.R919Gfs*14 | Frame Shift Del (DEL) | VAF 80/476 reads (17%) | catalogued as rs778275488, COSV53142223; called by mutect2, varscan2
- MAP4K4 | c.771del p.K257Nfs*10 | Frame Shift Del (DEL) | VAF 75/237 reads (32%) | catalogued as rs774203808; called by mutect2, pindel, varscan2
- MAP7D1 | c.211C>A p.P71T | Missense Mutation (SNP) | VAF 124/350 reads (35%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.138); catalogued as COSV60215551; called by mutect2, varscan2
- MAP7D1 | c.2407G>A p.G803R | Missense Mutation (SNP) | VAF 145/456 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs746024263; called by muse, mutect2, varscan2
- MAPK11 | c.518G>A p.R173H | Missense Mutation (SNP) | VAF 121/369 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57997660, COSV57998415; called by muse, mutect2, varscan2
- MARVELD2 | c.1550del p.K517Rfs*16 | Frame Shift Del (DEL) | VAF 43/77 reads (56%) | catalogued as rs753107989; called by mutect2, varscan2
- MAST4 | c.3497A>G p.D1166G (on ENST00000403625 / NM_001164664.2; = p.D977G on NM_015183.3) | Missense Mutation (SNP) | VAF 89/282 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55121796; called by muse, mutect2, varscan2
- MATN3 | c.18del p.A7Rfs*96 | Frame Shift Del (DEL) | VAF 89/319 reads (28%) | catalogued as rs1466789275; called by mutect2, pindel, varscan2
- MC2R | c.307G>A p.D103N | Missense Mutation (SNP) | VAF 128/375 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs768093045, CM002357; called by muse, mutect2, varscan2
- MCHR2 | c.623del p.F208Sfs*5 | Frame Shift Del (DEL) | VAF 50/138 reads (36%) | catalogued as rs759525627, COSV55999002; called by mutect2, varscan2
- MCM2 | c.452G>A p.R151H | Missense Mutation (SNP) | VAF 30/491 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs751729409, COSV54032639; called by muse, mutect2
- MDN1 | c.12373C>T p.R4125* | Nonsense Mutation (SNP) | VAF 133/367 reads (36%) | catalogued as rs1322121108, COSV65529519; called by muse, mutect2, varscan2
- MDN1 | c.8073del p.F2691Lfs*7 | Frame Shift Del (DEL) | VAF 109/324 reads (34%) | catalogued as rs35107588; called by mutect2, varscan2
- MEDAG | c.807del p.F269Lfs*11 | Frame Shift Del (DEL) | VAF 34/278 reads (12%) | catalogued as rs758005318; called by pindel, varscan2
- MELTF | c.916G>A p.E306K | Missense Mutation (SNP) | VAF 104/286 reads (36%) | SIFT tolerated (0.44); PolyPhen benign (0.04); catalogued as rs190096194, COSV56382588; called by muse, mutect2, varscan2
- METTL26 | c.451del p.Q151Rfs*8 | Frame Shift Del (DEL) | VAF 107/433 reads (25%) | catalogued as rs780007832; called by mutect2, pindel, varscan2
- MEX3D | c.1145G>A p.R382Q | Missense Mutation (SNP) | VAF 350/670 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.043); catalogued as COSV101183577; called by muse, mutect2, varscan2
- MGAT4C | c.1133T>G p.V378G | Missense Mutation (SNP) | VAF 67/180 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.058); catalogued as COSV100153527; called by muse, mutect2, varscan2
- MIER2 | c.1222G>A p.A408T | Missense Mutation (SNP) | VAF 14/496 reads (3%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs890049805; called by muse, mutect2
- MIXL1 | c.43G>A p.A15T | Missense Mutation (SNP) | VAF 53/320 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.531); catalogued as rs1455427393; called by muse, mutect2, varscan2
- MLLT6 | c.2087C>T p.A696V | Missense Mutation (SNP) | VAF 180/518 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.074); catalogued as rs745383731; called by mutect2, varscan2
- MMP24 | c.104T>G p.L35R | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.061); catalogued as rs1189001038; called by muse, varscan2
- MOB1B | c.567del p.F189Lfs*19 | Frame Shift Del (DEL) | VAF 48/196 reads (24%) | catalogued as rs778232663; called by mutect2, varscan2
- MOCOS | c.637del p.L213Cfs*4 | Frame Shift Del (DEL) | VAF 107/369 reads (29%) | catalogued as COSV54345674; called by pindel, varscan2
- MOCOS | c.686C>T p.T229M | Missense Mutation (SNP) | VAF 76/396 reads (19%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.607); catalogued as rs141623345; ClinVar: uncertain significance; called by muse, varscan2
- MON2 | c.935G>A p.R312H | Missense Mutation (SNP) | VAF 102/269 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1409435535, COSV54803293; called by muse, mutect2, varscan2
- MORC1 | c.2641del p.I881* | Frame Shift Del (DEL) | VAF 30/130 reads (23%) | catalogued as rs757379917; called by mutect2, varscan2
- MRGPRX3 | c.163C>T p.R55C | Missense Mutation (SNP) | VAF 151/472 reads (32%) | SIFT tolerated (0.24); PolyPhen benign (0.127); catalogued as rs370102882; called by muse, mutect2, varscan2
- MRPL18 | c.449C>T p.P150L | Missense Mutation (SNP) | VAF 94/297 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.142); catalogued as rs755403057, COSV51707013; called by muse, mutect2, varscan2
- MRRF | c.76G>A p.V26I | Missense Mutation (SNP) | VAF 109/341 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs140821991; called by muse, mutect2, varscan2
- MRTFB | c.2650dup p.R884Pfs*3 (on ENST00000571589 / NM_001365412.2; = p.R834Pfs*3 on NM_014048.4 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 88/319 reads (28%) | catalogued as rs768684761; called by mutect2, varscan2
- MSL2 | c.1429C>T p.R477* | Nonsense Mutation (SNP) | VAF 130/371 reads (35%) | catalogued as COSV53863076; called by muse, mutect2, varscan2
- MSLN | c.1693C>T p.R565C (on ENST00000382862 / NM_013404.4; = p.R557C on NM_005823.6) | Missense Mutation (SNP) | VAF 136/412 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.011); catalogued as rs140194589; called by muse, mutect2, varscan2
- MST1 | c.601C>T p.R201W | Missense Mutation (SNP) | VAF 91/271 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.761); catalogued as rs550893304; called by muse, mutect2, varscan2
- MTMR2 | c.1318C>T p.R440* | Nonsense Mutation (SNP) | VAF 88/297 reads (30%) | catalogued as rs751677491, COSV60579848; called by muse, mutect2, varscan2
- MTSS1 | c.1958G>A p.G653D | Missense Mutation (SNP) | VAF 166/808 reads (21%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.476); catalogued as rs1330212586; called by muse, mutect2, varscan2
- MTX1 | c.22del p.R8Afs*110 | Frame Shift Del (DEL) | VAF 112/293 reads (38%) | catalogued as rs755845788, COSV57426587; called by mutect2, varscan2
- MUC12 | c.7909A>G p.T2637A (on ENST00000379442; = p.T2494A on NM_001164462.1) | Missense Mutation (SNP) | VAF 108/2139 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.596); catalogued as COSV65204739; called by muse, mutect2
- MUC16 | c.34562C>A p.A11521D | Missense Mutation (SNP) | VAF 114/534 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.825); catalogued as COSV67475463; called by mutect2, varscan2
- MUC3A | c.940del p.L314Yfs*5 | Frame Shift Del (DEL) | VAF 141/521 reads (27%) | catalogued as COSV60222562; called by mutect2, pindel, varscan2
- MUC4 | c.10793C>T p.A3598V | Missense Mutation (SNP) | VAF 119/413 reads (29%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.494); catalogued as rs746820743; called by muse, mutect2, varscan2
- MVB12B | c.442A>G p.I148V | Missense Mutation (SNP) | VAF 37/258 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.191); catalogued as rs763539920; called by muse, mutect2, varscan2
- MYBPC2 | c.2143G>A p.A715T | Missense Mutation (SNP) | VAF 229/477 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); catalogued as rs776420780; called by muse, mutect2, varscan2
- MYBPH | c.1285C>T p.R429C | Missense Mutation (SNP) | VAF 125/408 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1169133037; called by muse, mutect2, varscan2
- MYH14 | c.2842G>A p.V948M | Missense Mutation (SNP) | VAF 171/577 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.036); catalogued as rs749286731, COSV51827421; called by muse, mutect2, varscan2
- MYH7B | c.451C>A p.R151S | Missense Mutation (SNP) | VAF 98/285 reads (34%) | SIFT tolerated (0.46); PolyPhen benign (0.007); catalogued as COSV99483423; called by muse, mutect2, varscan2
- MYO10 | c.3674del p.G1225Afs*22 | Frame Shift Del (DEL) | VAF 97/294 reads (33%) | catalogued as rs760302326; called by mutect2, varscan2
- MYO18B | c.530del p.P177Lfs*55 | Frame Shift Del (DEL) | VAF 100/308 reads (32%) | catalogued as rs748007891; called by mutect2, varscan2
- MYO1F | c.2573G>A p.R858H | Missense Mutation (SNP) | VAF 131/545 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.117); catalogued as rs1280824282; called by muse, mutect2, varscan2
- MYO7B | c.2990C>T p.P997L | Missense Mutation (SNP) | VAF 108/293 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1328515396; called by muse, mutect2, varscan2
- MYT1L | c.2485A>T p.I829L | Missense Mutation (SNP) | VAF 58/340 reads (17%) | SIFT tolerated (0.66); PolyPhen benign (0.009); catalogued as COSV67719422; called by muse, mutect2, varscan2
- N4BP2L1 | c.104_106del p.P35del | In Frame Del (DEL) | VAF 72/609 reads (12%) | catalogued as rs751381349; called by pindel, varscan2
- NAA16 | c.868G>A p.A290T | Missense Mutation (SNP) | VAF 78/218 reads (36%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.904); catalogued as rs757352237, COSV101038269; called by muse, mutect2, varscan2
- NAA25 | c.1013G>A p.G338D | Missense Mutation (SNP) | VAF 101/287 reads (35%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.883); catalogued as rs759753817; called by muse, mutect2, varscan2
- NADK | c.687G>T p.E229D | Missense Mutation (SNP) | VAF 64/232 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.077); catalogued as COSV100411172; called by muse, mutect2, varscan2
- NANOS1 | c.517G>A p.A173T | Missense Mutation (SNP) | VAF 80/196 reads (41%) | SIFT tolerated (0.63); PolyPhen benign (0.007); catalogued as rs1183027799, CD131459, COSV60775608; called by muse, varscan2
- NARS2 | c.947del p.N316Tfs*4 | Frame Shift Del (DEL) | VAF 9/26 reads (35%) | catalogued as rs755975670; called by mutect2, pindel, varscan2
- NBR1 | c.2236del p.L746Wfs*50 | Frame Shift Del (DEL) | VAF 143/406 reads (35%) | catalogued as rs34660735; called by mutect2, varscan2
- NCKAP1 | c.3179C>T p.A1060V | Missense Mutation (SNP) | VAF 57/198 reads (29%) | SIFT tolerated (0.47); PolyPhen benign (0.013); catalogued as rs763472368, COSV62943255; called by muse, mutect2, varscan2
- NDUFA10 | c.604del p.H202Tfs*3 | Frame Shift Del (DEL) | VAF 108/413 reads (26%) | catalogued as rs746019378; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- NDUFB9 | c.529C>T p.R177W | Missense Mutation (SNP) | VAF 124/359 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.355); catalogued as rs1425123491; called by muse, mutect2, varscan2
- NEB | c.12274C>T p.P4092S | Missense Mutation (SNP) | VAF 84/286 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs758782126; called by muse, mutect2, varscan2
- NEFM | c.2340G>T p.E780D | Missense Mutation (SNP) | VAF 143/463 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.052); catalogued as COSV55332218; called by muse, mutect2, varscan2
- NEK1 | c.2556del p.V853Yfs*8 | Frame Shift Del (DEL) | VAF 56/196 reads (29%) | catalogued as rs760894879; called by mutect2, varscan2
- NELFB | c.1207A>T p.I403F | Missense Mutation (SNP) | VAF 150/438 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs1372442201; called by muse, mutect2, varscan2
- NEU4 | c.742C>T p.R248C (on ENST00000391969 / NM_001167602.3; = p.R260C on NM_080741.4) | Missense Mutation (SNP) | VAF 227/571 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755490713; called by muse, mutect2, varscan2
- NEU4 | c.1280C>T p.P427L (on ENST00000391969 / NM_001167602.3; = p.P439L on NM_080741.4) | Missense Mutation (SNP) | VAF 233/635 reads (37%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as rs770027529; called by muse, mutect2, varscan2
- NEUROG1 | c.11G>A p.R4H | Missense Mutation (SNP) | VAF 79/262 reads (30%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.093); catalogued as rs1273192291; called by muse, mutect2, varscan2
- NFKBIB | c.458G>A p.R153H | Missense Mutation (SNP) | VAF 124/572 reads (22%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs746674509, COSV100548268; called by muse, mutect2, varscan2
- NHSL1 | c.4183G>A p.G1395S | Missense Mutation (SNP) | VAF 117/372 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.047); catalogued as rs1253213091; called by muse, mutect2, varscan2
- NIBAN2 | c.189G>A p.V63= | Splice Region (SNP) | VAF 52/197 reads (26%) | catalogued as rs762346243; called by muse, mutect2, varscan2
- NID2 | c.3659G>A p.R1220H | Missense Mutation (SNP) | VAF 153/393 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781075786; called by muse, mutect2, varscan2
- NIM1K | c.875C>T p.P292L | Missense Mutation (SNP) | VAF 130/380 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.067); catalogued as rs201716824, COSV100389965, COSV100390118; called by muse, varscan2
- NKX2-6 | c.611C>T p.T204M | Missense Mutation (SNP) | VAF 153/432 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.223); catalogued as rs1343114635, COSV100273976; called by muse, mutect2, varscan2
- NLRP2 | c.3113del p.N1038Tfs*4 | Frame Shift Del (DEL) | VAF 77/344 reads (22%) | catalogued as rs745782532; called by mutect2, varscan2
- NLRP4 | c.1258C>T p.R420W | Missense Mutation (SNP) | VAF 121/541 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs140509890, COSV100016724, COSV56715578; called by muse, mutect2, varscan2
- NLRP5 | c.2038A>G p.T680A | Missense Mutation (SNP) | VAF 142/558 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1023345519, COSV66763247; called by muse, mutect2, varscan2
- NLRP6 | c.2658G>T p.K886N | Missense Mutation (SNP) | VAF 113/297 reads (38%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.055); catalogued as rs1418961532; called by muse, mutect2, varscan2
- NME8 | c.905C>T p.A302V | Missense Mutation (SNP) | VAF 157/334 reads (47%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV52253326; called by muse, mutect2, varscan2
- NOBOX | c.1322del p.P441Hfs*25 | Frame Shift Del (DEL) | VAF 30/82 reads (37%) | catalogued as rs753934412; called by mutect2, pindel, varscan2
- NOM1 | c.683del p.N228Ifs*24 | Frame Shift Del (DEL) | VAF 83/448 reads (19%) | catalogued as rs1047398041, COSV51979717; called by mutect2, pindel, varscan2
- NOTCH3 | c.5323G>A p.A1775T | Missense Mutation (SNP) | VAF 241/491 reads (49%) | SIFT tolerated (0.44); PolyPhen benign (0.03); catalogued as rs139983430; called by muse, mutect2, varscan2
- NPHS1 | c.3554del p.P1185Rfs*52 | Frame Shift Del (DEL) | VAF 74/358 reads (21%) | catalogued as COSV100800437, COSV62287222; called by mutect2, pindel, varscan2
- NPS | c.244del p.T82Lfs*10 | Frame Shift Del (DEL) | VAF 78/305 reads (26%) | catalogued as rs1455620486; called by mutect2, pindel, varscan2
- NPTX1 | c.667C>T p.R223C | Missense Mutation (SNP) | VAF 86/228 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); catalogued as COSV60775101; called by muse, mutect2, varscan2
- NSD2 | c.2831G>C p.R944P | Missense Mutation (SNP) | VAF 141/407 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV56393044; called by muse, mutect2, varscan2
- NTRK2 | c.2026G>A p.D676N (on ENST00000323115 / NM_001369534.1; = p.D692N on NM_006180.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 114/398 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52871416; called by muse, mutect2, varscan2
- NUMA1 | c.5295del p.K1766Rfs*2 | Frame Shift Del (DEL) | VAF 159/484 reads (33%) | catalogued as rs1207322636, COSV52621264; called by mutect2, pindel, varscan2
- NUP85 | c.1475G>A p.R492H | Missense Mutation (SNP) | VAF 102/297 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs545929051, COSV99822345; called by muse, mutect2, varscan2
- NUP88 | c.1796del p.K599Rfs*4 | Frame Shift Del (DEL) | VAF 49/182 reads (27%) | catalogued as rs1396162133; called by mutect2, pindel, varscan2
- NYX | c.626G>A p.R209H | Missense Mutation (SNP) | VAF 196/266 reads (74%) | SIFT tolerated (0.15); PolyPhen benign (0.142); catalogued as rs760900596, CM152088; called by muse, mutect2, varscan2
- OAS3 | c.1970C>T p.T657M | Missense Mutation (SNP) | VAF 98/356 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs200778728; called by muse, mutect2, varscan2
- OGFRL1 | c.914C>T p.T305M | Missense Mutation (SNP) | VAF 129/397 reads (32%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.928); catalogued as rs373599406; called by muse, mutect2, varscan2
- ONECUT3 | c.29del p.G10Afs*14 | Frame Shift Del (DEL) | VAF 45/231 reads (19%) | catalogued as rs1335499382; called by mutect2, pindel, varscan2
- OPLAH | c.1520C>T p.T507M | Missense Mutation (SNP) | VAF 221/539 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.243); catalogued as rs369275033; called by muse, mutect2, varscan2
- OR11H12 | c.355T>C p.F119L | Missense Mutation (SNP) | VAF 104/764 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV101612534; called by muse, varscan2
- OR13C3 | c.737del p.F246Sfs*13 | Frame Shift Del (DEL) | VAF 59/398 reads (15%) | catalogued as rs764206746; called by mutect2, pindel, varscan2
- OR2B3 | c.708del p.A237Hfs*9 | Frame Shift Del (DEL) | VAF 193/647 reads (30%) | catalogued as COSV65851036; called by mutect2, pindel, varscan2
- OR2B3 | c.290G>A p.C97Y | Missense Mutation (SNP) | VAF 233/678 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101013773; called by muse, mutect2, varscan2
- OR2T35 | c.821T>C p.V274A | Missense Mutation (SNP) | VAF 79/406 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.506); catalogued as rs1202881230; called by muse, varscan2
- OR51A2 | c.521A>C p.N174T | Missense Mutation (SNP) | VAF 108/317 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.052); catalogued as rs1253380183; called by muse, mutect2, varscan2
- OR51E2 | c.467del p.F156Sfs*6 | Frame Shift Del (DEL) | VAF 112/368 reads (30%) | catalogued as rs755413956; called by mutect2, varscan2
- OR51G1 | c.679G>A p.V227M | Missense Mutation (SNP) | VAF 66/216 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs759143429, COSV58971104; called by muse, mutect2, varscan2
- OR5AR1 | c.924del p.K308Nfs*8 | Frame Shift Del (DEL) | VAF 48/170 reads (28%) | catalogued as rs1179572364; called by mutect2, pindel, varscan2
- OR5T2 | c.1077del p.K359Nfs*4 | Frame Shift Del (DEL) | VAF 44/157 reads (28%) | catalogued as rs768492646; called by mutect2, pindel, varscan2
- OR5V1 | c.758G>A p.G253D | Missense Mutation (SNP) | VAF 117/371 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs111683139; called by muse, mutect2, varscan2
- OR6P1 | c.96del p.F32Lfs*6 | Frame Shift Del (DEL) | VAF 110/280 reads (39%) | catalogued as rs201077183; called by mutect2, varscan2
- OR6T1 | c.947T>C p.L316P | Missense Mutation (SNP) | VAF 45/275 reads (16%) | SIFT tolerated (0.36); PolyPhen benign (0.233); catalogued as COSV58306488, COSV58309678; called by muse, mutect2, varscan2
- OR6V1 | c.106G>A p.A36T | Missense Mutation (SNP) | VAF 149/499 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.019); catalogued as rs757175682, COSV69237599; called by muse, mutect2, varscan2
- ORC4 | c.850A>G p.M284V | Missense Mutation (SNP) | VAF 73/183 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0.009); catalogued as rs752155802; called by muse, mutect2, varscan2
- OTULIN | c.895C>T p.R299C | Missense Mutation (SNP) | VAF 121/343 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs771800109, COSV52505510; called by muse, mutect2, varscan2
- OXNAD1 | c.725G>A p.S242N | Missense Mutation (SNP) | VAF 94/293 reads (32%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.473); catalogued as rs772740883, COSV53266530; called by muse, mutect2, varscan2
- PABPC1 | c.1109G>A p.R370H | Missense Mutation (SNP) | VAF 119/707 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs777648449, COSV100589947; called by muse, varscan2
- PADI1 | c.1681G>A p.A561T | Missense Mutation (SNP) | VAF 88/258 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs752194968; called by muse, mutect2, varscan2
- PADI2 | c.754G>A p.V252M | Missense Mutation (SNP) | VAF 139/410 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs192937557, COSV100971118; called by muse, mutect2, varscan2
- PALB2 | c.886del p.M296* | Frame Shift Del (DEL) | VAF 108/264 reads (41%) | catalogued as CD147527; called by mutect2, varscan2
- PAN2 | c.3337C>T p.R1113* (on ENST00000425394 / NM_001127460.3; = p.R1109* on NM_014871.5) | Nonsense Mutation (SNP) | VAF 115/328 reads (35%) | catalogued as rs771809067; called by muse, mutect2, varscan2
- PANK1 | c.307A>G p.N103D | Missense Mutation (SNP) | VAF 155/437 reads (35%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as COSV100285539; called by muse, mutect2, varscan2
- PARN | c.1684A>G p.S562G | Missense Mutation (SNP) | VAF 124/356 reads (35%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.001); catalogued as rs767471431; called by muse, mutect2
- PARP4 | c.3761A>G p.Q1254R | Missense Mutation (SNP) | VAF 84/398 reads (21%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV67961544; called by muse, mutect2, varscan2
- PAX2 | c.11A>G p.H4R | Missense Mutation (SNP) | VAF 117/374 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); catalogued as COSV62290819; called by muse, mutect2, varscan2
- PAX5 | c.76dup p.V26Gfs*49 | Frame Shift Ins (INS) | VAF 190/298 reads (64%) | catalogued as rs767894241; called by mutect2, varscan2
- PAX6 | c.1124dup p.H376Tfs*36 | Frame Shift Ins (INS) | VAF 118/330 reads (36%) | catalogued as rs756801119; called by mutect2, varscan2
- PCDH10 | c.1943G>A p.R648H | Missense Mutation (SNP) | VAF 148/433 reads (34%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.998); catalogued as COSV52089594; called by muse, varscan2
- PCDH15 | c.4252G>A p.A1418T | Missense Mutation (SNP) | VAF 120/323 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); catalogued as COSV57303574; called by muse, varscan2
- PCDH18 | c.712G>A p.D238N | Missense Mutation (SNP) | VAF 96/288 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100787456; called by muse, mutect2, varscan2
- PCDHA13 | c.1991C>T p.T664M | Missense Mutation (SNP) | VAF 125/311 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as rs1554181391, COSV99164889; called by muse, mutect2, varscan2
- PCDHA6 | c.1870G>A p.V624M | Missense Mutation (SNP) | VAF 115/354 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); catalogued as COSV65343443; called by muse, mutect2, varscan2
- PCDHA7 | c.140G>A p.R47H | Missense Mutation (SNP) | VAF 168/506 reads (33%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.421); catalogued as COSV65345970; called by muse, mutect2, varscan2
- PCDHGA2 | c.1873G>A p.E625K | Missense Mutation (SNP) | VAF 218/618 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.972); catalogued as COSV53906010; called by muse, mutect2, varscan2
- PCDHGB3 | c.1912G>A p.A638T | Missense Mutation (SNP) | VAF 132/393 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0.354); catalogued as rs771102617, COSV54016059; called by muse, varscan2
- PCDHGC3 | c.2066del p.N689Ifs*10 | Frame Shift Del (DEL) | VAF 106/330 reads (32%) | catalogued as rs1156842877; called by mutect2, varscan2
- PCLO | c.12055A>T p.S4019C | Missense Mutation (SNP) | VAF 102/344 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV100434242; called by muse, mutect2, varscan2
- PCLO | c.11945G>A p.R3982H | Missense Mutation (SNP) | VAF 105/310 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); catalogued as rs371334306; called by muse, mutect2, varscan2
- PCNX3 | c.1446del p.K483Sfs*22 | Frame Shift Del (DEL) | VAF 150/454 reads (33%) | catalogued as COSV58419661; called by mutect2, varscan2
- PDCL | c.856C>T p.R286C | Missense Mutation (SNP) | VAF 71/249 reads (29%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.75); catalogued as rs762726299, COSV52342197, COSV99414126; called by muse, mutect2, varscan2
- PDE11A | c.62del p.K21Rfs*2 | Frame Shift Del (DEL) | VAF 103/347 reads (30%) | catalogued as COSV61773784; called by mutect2, pindel, varscan2
- PDGFD | c.640del p.I214Lfs*68 | Frame Shift Del (DEL) | VAF 67/301 reads (22%) | catalogued as rs1333395128; called by mutect2, pindel, varscan2
- PDS5B | c.3860dup p.K1289* | Frame Shift Ins (INS) | VAF 98/386 reads (25%) | catalogued as rs1286544933; called by mutect2, varscan2
- PEAR1 | c.1172G>A p.C391Y | Missense Mutation (SNP) | VAF 164/497 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1215687860; called by muse, mutect2, varscan2
- PFN2 | c.113del p.G38Afs*9 | Frame Shift Del (DEL) | VAF 102/336 reads (30%) | catalogued as rs1272983738; called by mutect2, pindel, varscan2
- PGAP4 | c.295del p.R99Gfs*5 | Frame Shift Del (DEL) | VAF 140/484 reads (29%) | catalogued as rs765092936; called by mutect2, varscan2
- PGF | c.352G>A p.V118M | Missense Mutation (SNP) | VAF 112/390 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.608); catalogued as rs140548843; called by muse, mutect2, varscan2
- PGGT1B | c.616T>C p.Y206H | Missense Mutation (SNP) | VAF 70/210 reads (33%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.736); catalogued as rs1250467527; called by muse, mutect2, varscan2
- PHACTR2 | c.1723C>T p.R575* | Nonsense Mutation (SNP) | VAF 92/292 reads (32%) | catalogued as rs761764697; called by muse, mutect2, varscan2
- PHC1 | c.2578C>T p.R860C | Missense Mutation (SNP) | VAF 101/300 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs757860354, COSV99134161; called by muse, mutect2, varscan2
- PHYHIP | c.634C>T p.R212C | Missense Mutation (SNP) | VAF 185/482 reads (38%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.71); catalogued as rs1003276981, COSV58688390; called by muse, mutect2, varscan2
- PIEZO1 | c.4381C>T p.R1461W | Missense Mutation (SNP) | VAF 111/334 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.528); catalogued as rs756761414, COSV56340893; called by muse, mutect2, varscan2
- PIEZO1 | c.988C>T p.R330C | Missense Mutation (SNP) | VAF 119/365 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.27); catalogued as rs546108970; called by muse, mutect2, varscan2
- PIK3C3 | c.531+9dup | Splice Region (INS) | VAF 111/404 reads (27%) | catalogued as rs772354291; called by mutect2, varscan2
- PIP4P2 | c.538del p.I180Sfs*21 | Frame Shift Del (DEL) | VAF 62/354 reads (18%) | catalogued as rs1158949501; called by mutect2, pindel, varscan2
- PIWIL2 | c.2048C>T p.A683V | Missense Mutation (SNP) | VAF 134/440 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.823); catalogued as COSV63254408; called by muse, mutect2, varscan2
- PKN2 | c.1006A>T p.M336L | Missense Mutation (SNP) | VAF 95/259 reads (37%) | SIFT tolerated (0.82); PolyPhen benign (0.001); catalogued as rs779473256; called by muse, mutect2, varscan2
- PKP4 | c.2281C>T p.R761W | Missense Mutation (SNP) | VAF 116/340 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as rs766210177; called by muse, mutect2, varscan2
- PLA2G6 | c.1934G>A p.R645Q | Missense Mutation (SNP) | VAF 143/417 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs780784951; called by muse, mutect2, varscan2
- PLCD1 | c.226C>T p.R76* | Nonsense Mutation (SNP) | VAF 100/256 reads (39%) | catalogued as rs1335830144; called by mutect2, varscan2
- PLCD3 | c.436C>T p.R146C | Missense Mutation (SNP) | VAF 171/542 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.23); catalogued as rs1394109717; called by muse, mutect2, varscan2
- PLEC | c.6388A>G p.S2130G (on ENST00000322810 / NM_201380.4; = p.S2020G on NM_000445.5) | Missense Mutation (SNP) | VAF 206/860 reads (24%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.069); catalogued as rs782436266; called by muse, mutect2, varscan2
- PLEKHA6 | c.1406G>A p.R469H | Missense Mutation (SNP) | VAF 169/511 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as rs572115695; called by muse, mutect2, varscan2
- PLEKHG3 | c.698T>C p.L233P (on ENST00000394691; = p.L289P on NM_001308147.2) | Missense Mutation (SNP) | VAF 96/270 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55982615; called by muse, mutect2, varscan2
- PLEKHG3 | c.3223T>C p.Y1075H (on ENST00000394691; = p.Y1131H on NM_001308147.2) | Missense Mutation (SNP) | VAF 158/470 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as rs1399369766; called by muse, mutect2, varscan2
- PLG | c.1229A>G p.Q410R | Missense Mutation (SNP) | VAF 95/269 reads (35%) | SIFT tolerated (0.36); PolyPhen benign (0.01); catalogued as rs757425055; called by muse, mutect2, varscan2
- PLXNA1 | c.5630G>A p.R1877Q | Missense Mutation (SNP) | VAF 137/362 reads (38%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.638); catalogued as rs144688057; called by muse, mutect2, varscan2
- PLXNA2 | c.2203C>T p.R735* | Nonsense Mutation (SNP) | VAF 128/353 reads (36%) | catalogued as rs150244971; called by muse, varscan2
- PLXNA4 | c.4127G>A p.R1376H | Missense Mutation (SNP) | VAF 119/385 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs750458788, COSV58102490; called by muse, mutect2, varscan2
- PLXNB1 | c.1828G>A p.V610M | Missense Mutation (SNP) | VAF 38/224 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as rs377145799; called by muse, mutect2, varscan2
- PLXNB1 | c.536del p.G179Vfs*41 | Frame Shift Del (DEL) | VAF 149/447 reads (33%) | catalogued as rs953293505; called by mutect2, varscan2
- PLXNC1 | c.397G>A p.A133T | Missense Mutation (SNP) | VAF 191/500 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs1442291470, COSV99313159; called by muse, mutect2, varscan2
- PLXND1 | c.2022dup p.N675Qfs*8 | Frame Shift Ins (INS) | VAF 92/266 reads (35%) | catalogued as rs747702371; called by mutect2, varscan2
- PNMA6F | c.1727del p.P576Rfs*6 | Frame Shift Del (DEL) | VAF 84/141 reads (60%) | catalogued as rs1569527424; called by mutect2, pindel, varscan2
- PNMA8B | c.673G>A p.A225T | Missense Mutation (SNP) | VAF 292/589 reads (50%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.809); catalogued as rs1258317784; called by muse, mutect2, varscan2
- PODN | c.68G>A p.R23H | Missense Mutation (SNP) | VAF 134/350 reads (38%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.018); catalogued as rs942279747; called by mutect2, varscan2
- POLR1A | c.154G>A p.D52N | Missense Mutation (SNP) | VAF 163/457 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs912231804, COSV55699165; called by muse, mutect2, varscan2
- POLR2B | c.916G>A p.D306N | Missense Mutation (SNP) | VAF 69/220 reads (31%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.982); catalogued as rs1319666522, COSV58900857; called by muse, mutect2, varscan2
- POLR2F | c.151C>T p.R51* | Nonsense Mutation (SNP) | VAF 135/401 reads (34%) | catalogued as rs752411216, COSV68091719; called by muse, mutect2, varscan2
- POM121 | c.1330C>T p.R444C (on ENST00000434423; = p.R179C on NM_172020.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 85/373 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.03); catalogued as rs375481294, COSV57518089, COSV57525087; called by muse, mutect2, varscan2
- PPP1CA | c.533del p.P178Rfs*74 | Frame Shift Del (DEL) | VAF 77/273 reads (28%) | catalogued as COSV100334758, COSV100334977; called by mutect2, pindel, varscan2
- PPP1R12C | c.1110del p.I373Sfs*51 | Frame Shift Del (DEL) | VAF 232/611 reads (38%) | catalogued as COSV54738562; called by mutect2, pindel, varscan2
- PPP4R3B | c.2259del p.A754Qfs*38 (on ENST00000616407 / NM_001122964.3; = p.A669Qfs*38 on NM_020463.4) | Frame Shift Del (DEL) | VAF 49/174 reads (28%) | catalogued as COSV55409118; called by mutect2, pindel, varscan2
- PPT1 | c.800G>A p.R267H (on ENST00000433473; = p.R268H on NM_000310.4) | Missense Mutation (SNP) | VAF 77/255 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.047); catalogued as rs763536047, COSV61222920, COSV61223230; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PRAMEF14 | c.1001G>A p.R334H | Missense Mutation (SNP) | VAF 99/387 reads (26%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs770729312; called by muse, mutect2, varscan2
- PRDM14 | c.193G>A p.A65T | Missense Mutation (SNP) | VAF 152/868 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as rs747860295; called by muse, mutect2, varscan2
- PRDM2 | c.931C>T p.R311W | Missense Mutation (SNP) | VAF 77/273 reads (28%) | SIFT tolerated, low confidence (0.19); PolyPhen probably damaging (0.922); catalogued as rs751199033, COSV99341286; called by muse, mutect2, varscan2
- PREX2 | c.1693del p.S565Rfs*10 | Frame Shift Del (DEL) | VAF 156/378 reads (41%) | catalogued as rs764112302; called by mutect2, varscan2
- PRKAR1B | c.716C>T p.T239M | Missense Mutation (SNP) | VAF 94/384 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV64319594; called by muse, mutect2, varscan2
- PRLHR | c.824G>A p.R275H | Missense Mutation (SNP) | VAF 164/461 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99492672, COSV99492778; called by muse, mutect2
- PRLHR | c.22G>A p.G8S | Missense Mutation (SNP) | VAF 39/275 reads (14%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as rs762835879; called by muse, mutect2, varscan2
- PROB1 | c.235C>T p.R79C | Missense Mutation (SNP) | VAF 174/506 reads (34%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.019); catalogued as rs145817341; called by muse, mutect2, varscan2
- PROSER2 | c.788C>T p.A263V | Missense Mutation (SNP) | VAF 188/534 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.373); catalogued as COSV53205631; called by muse, mutect2, varscan2
- PRR12 | c.71C>A p.P24H (on ENST00000615927; = p.P845H on NM_020719.3) | Missense Mutation (SNP) | VAF 80/526 reads (15%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.533); catalogued as COSV69820232; called by muse, mutect2, varscan2
- PRR30 | c.1196G>T p.R399M | Missense Mutation (SNP) | VAF 161/461 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.929); catalogued as rs1226829511; called by muse, mutect2, varscan2
- PSD | c.785dup p.S263Ifs*38 | Frame Shift Ins (INS) | VAF 128/370 reads (35%) | catalogued as rs768369085; called by mutect2, varscan2
- PSME4 | c.3626C>T p.A1209V | Missense Mutation (SNP) | VAF 72/213 reads (34%) | SIFT tolerated (0.24); PolyPhen benign (0.057); catalogued as rs763076906; called by muse, mutect2, varscan2
- PSME4 | c.3551G>A p.R1184H | Missense Mutation (SNP) | VAF 106/302 reads (35%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.54); catalogued as rs200270494; called by muse, mutect2, varscan2
- PTCH2 | c.1244G>A p.R415Q | Missense Mutation (SNP) | VAF 150/403 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs764488358, COSV64711571; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PTGDR | c.700C>T p.R234W | Missense Mutation (SNP) | VAF 169/463 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.766); catalogued as rs199602538; called by muse, mutect2, varscan2
- PTH1R | c.52G>A p.V18M | Missense Mutation (SNP) | VAF 112/352 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.025); catalogued as rs772304416; called by muse, varscan2
- PTPN21 | c.1247C>T p.S416L | Missense Mutation (SNP) | VAF 135/407 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV60846542; called by muse, mutect2, varscan2
- PTPN4 | c.1403_1406del p.K468Sfs*19 | Frame Shift Del (DEL) | VAF 86/312 reads (28%) | catalogued as rs758611912; called by mutect2, pindel, varscan2
- PTPRF | c.1376del p.P459Rfs*101 | Frame Shift Del (DEL) | VAF 168/569 reads (30%) | catalogued as rs1553196047; called by mutect2, pindel, varscan2
- PXDN | c.2635G>A p.V879M | Missense Mutation (SNP) | VAF 111/350 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs765506698; called by muse, varscan2
- PXDNL | c.1127A>T p.H376L | Missense Mutation (SNP) | VAF 172/673 reads (26%) | SIFT tolerated (0.46); PolyPhen benign (0.017); catalogued as COSV100680802; called by muse, mutect2, varscan2
- PXMP2 | c.479C>T p.T160M | Missense Mutation (SNP) | VAF 133/362 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs747155657; called by muse, mutect2, varscan2
- PXN | c.1592G>A p.R531H (on ENST00000228307 / NM_001080855.3; = p.R497H on NM_002859.4) | Missense Mutation (SNP) | VAF 133/395 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs753638480; called by muse, mutect2, varscan2
- PYGL | c.1768C>T p.R590C | Missense Mutation (SNP) | VAF 85/237 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs562250944, COSV53588107; called by muse, mutect2, varscan2
- PYGO2 | c.329T>C p.M110T | Missense Mutation (SNP) | VAF 161/461 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs1218346921; called by muse, mutect2, varscan2
- QARS1 | c.1279C>T p.R427C | Missense Mutation (SNP) | VAF 44/202 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.284); catalogued as rs746114521; called by muse, varscan2
- R3HDML | c.158G>A p.R53H | Missense Mutation (SNP) | VAF 157/479 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs891194458, COSV53836305; called by muse, mutect2, varscan2
- RAB11FIP4 | c.145G>A p.G49S | Missense Mutation (SNP) | VAF 68/242 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.027); catalogued as COSV57930052; called by muse, varscan2
- RAB11FIP4 | c.1201G>A p.A401T | Missense Mutation (SNP) | VAF 92/504 reads (18%) | SIFT tolerated (0.87); PolyPhen benign (0.003); catalogued as rs1195561329; called by muse, mutect2, varscan2
- RAC3 | c.571G>A p.V191I | Missense Mutation (SNP) | VAF 94/238 reads (39%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0); catalogued as rs1229366485, COSV60712752; called by muse, mutect2, varscan2
- RAD50 | c.577C>T p.R193W | Missense Mutation (SNP) | VAF 49/167 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs28903087, CM068745; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RAD51B | c.920G>A p.R307Q | Missense Mutation (SNP) | VAF 96/358 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs34829418; called by muse, mutect2, varscan2
- RASA1 | c.2513del p.N838Mfs*4 | Frame Shift Del (DEL) | VAF 28/125 reads (22%) | catalogued as rs1561325048; called by mutect2, pindel, varscan2
- RASGEF1C | c.1051C>T p.R351C | Missense Mutation (SNP) | VAF 133/399 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.877); catalogued as rs760031898, COSV63186161; called by muse, mutect2, varscan2
- RBM19 | c.2584C>T p.R862C | Missense Mutation (SNP) | VAF 91/303 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs138978572; called by muse, mutect2, varscan2
- RCOR1 | c.376C>T p.R126C | Missense Mutation (SNP) | VAF 106/324 reads (33%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.623); catalogued as rs775741097; called by muse, mutect2, varscan2
- RD3 | c.434G>A p.R145Q | Missense Mutation (SNP) | VAF 17/561 reads (3%) | SIFT tolerated (0.12); PolyPhen benign (0.402); catalogued as COSV100879201; called by muse, mutect2
- RDH16 | c.785C>T p.S262L | Missense Mutation (SNP) | VAF 129/367 reads (35%) | SIFT tolerated (0.22); PolyPhen benign (0.134); catalogued as rs1270327031; called by muse, mutect2, varscan2
- REPS2 | c.298C>T p.R100W | Missense Mutation (SNP) | VAF 111/145 reads (77%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.948); catalogued as rs779056454; called by muse, mutect2, varscan2
- REST | c.1889C>T p.P630L | Missense Mutation (SNP) | VAF 162/518 reads (31%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as rs144905338; called by muse, mutect2
- RETREG2 | c.61_66del p.S21_L22del | In Frame Del (DEL) | VAF 111/357 reads (31%) | catalogued as rs1215545885; called by mutect2, pindel, varscan2
- REV3L | c.6331G>A p.D2111N | Missense Mutation (SNP) | VAF 64/343 reads (19%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs1355988871; called by muse, mutect2, varscan2
- RFX1 | c.107C>T p.A36V | Missense Mutation (SNP) | VAF 140/568 reads (25%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.001); catalogued as rs763661107; called by muse, mutect2, varscan2
- RFXANK | c.478G>A p.A160T | Missense Mutation (SNP) | VAF 200/441 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as rs780019385, COSV57393150; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RGS20 | c.371C>T p.P124L | Missense Mutation (SNP) | VAF 149/759 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as rs761634796; called by muse, mutect2, varscan2
- RGS3 | c.3058C>T p.R1020W (on ENST00000350696 / NM_001282923.2; = p.R739W on NM_130795.4) | Missense Mutation (SNP) | VAF 123/370 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.409); catalogued as rs971366874; called by muse, mutect2, varscan2
- RHBDD3 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 91/300 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.057); catalogued as rs753345361; called by muse, mutect2, varscan2
- RHOU | c.629del p.N210Tfs*34 | Frame Shift Del (DEL) | VAF 138/407 reads (34%) | catalogued as COSV64208296; called by mutect2, pindel, varscan2
- RIMS2 | c.995G>A p.R332H (on ENST00000666250 / NM_001348490.2; = p.R140H on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 152/670 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51686773; called by muse, mutect2, varscan2
- RING1 | c.517dup p.E173Gfs*21 | Frame Shift Ins (INS) | VAF 145/471 reads (31%) | catalogued as rs761874510; called by mutect2, varscan2
- RND1 | c.337G>T p.D113Y | Missense Mutation (SNP) | VAF 105/306 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV104399760; called by muse, mutect2, varscan2
- RNF128 | c.648del p.F216Lfs*32 (on ENST00000255499 / NM_194463.2; = p.F190Lfs*32 on NM_024539.3) | Frame Shift Del (DEL) | VAF 107/190 reads (56%) | catalogued as rs746331232, COSV55251573; called by mutect2, pindel, varscan2
- RNF130 | c.907A>G p.M303V | Missense Mutation (SNP) | VAF 101/291 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.531); catalogued as rs893144933; called by muse, mutect2, varscan2
- RNF216 | c.1700C>T p.S567L (on ENST00000425013 / NM_207116.3; = p.S624L on NM_207111.4) | Missense Mutation (SNP) | VAF 125/441 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.208); catalogued as rs757793877; called by muse, mutect2, varscan2
- RNF4 | c.58A>G p.T20A | Missense Mutation (SNP) | VAF 63/256 reads (25%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV58643033; called by muse, mutect2, varscan2
- ROR2 | c.445G>A p.V149I | Missense Mutation (SNP) | VAF 96/287 reads (33%) | SIFT tolerated (0.37); PolyPhen benign (0.431); catalogued as rs749699077; called by muse, mutect2, varscan2
- RP1L1 | c.839C>A p.P280H | Missense Mutation (SNP) | VAF 158/548 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.047); catalogued as COSV66760782; called by muse, mutect2, varscan2
- RPRD2 | c.1504_1506del p.T502del | In Frame Del (DEL) | VAF 100/352 reads (28%) | catalogued as rs1560224784; called by pindel, varscan2
- RPS6KA5 | c.1205G>A p.R402H | Missense Mutation (SNP) | VAF 78/265 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as rs1011167649; called by muse, mutect2, varscan2
- RPUSD2 | c.1088G>A p.R363Q | Missense Mutation (SNP) | VAF 146/425 reads (34%) | SIFT tolerated (0.39); PolyPhen benign (0.026); catalogued as rs1408443971; called by muse, mutect2, varscan2
- RREB1 | c.2522C>T p.A841V | Missense Mutation (SNP) | VAF 178/521 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.148); catalogued as rs778172996, COSV100619808; called by muse, mutect2, varscan2
- RREB1 | c.3712T>G p.S1238A | Missense Mutation (SNP) | VAF 113/362 reads (31%) | SIFT tolerated (0.89); PolyPhen benign (0.003); catalogued as rs1561799780; called by muse, mutect2, varscan2
- RTKN | c.1412G>A p.R471Q (on ENST00000272430 / NM_001015055.2; = p.R458Q on NM_033046.2) | Missense Mutation (SNP) | VAF 160/414 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as rs771739969, COSV99269449, COSV99270082; called by muse, mutect2, varscan2
- RTN4RL2 | c.1118dup p.Y374Lfs*4 | Frame Shift Ins (INS) | VAF 89/399 reads (22%) | catalogued as rs766724291; called by mutect2, varscan2
- RUSC2 | c.554G>A p.C185Y | Missense Mutation (SNP) | VAF 152/427 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0.189); catalogued as COSV63427989; called by muse, varscan2
- RYR3 | c.10957G>A p.A3653T (on ENST00000389232; = p.A3654T on NM_001036.6) | Missense Mutation (SNP) | VAF 129/333 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.328); catalogued as rs760230405; called by muse, mutect2, varscan2
- SAFB2 | c.2471dup p.Y825Lfs*9 | Frame Shift Ins (INS) | VAF 54/414 reads (13%) | catalogued as rs759920279; called by mutect2, varscan2
- SALL3 | c.3523C>T p.R1175C | Missense Mutation (SNP) | VAF 174/530 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs756550099, COSV73306220; called by muse, mutect2, varscan2
- SALL4 | c.2983del p.V995Ffs*14 | Frame Shift Del (DEL) | VAF 102/407 reads (25%) | catalogued as rs753320334; called by mutect2, varscan2
- SAMD9 | c.3640A>G p.I1214V | Missense Mutation (SNP) | VAF 58/204 reads (28%) | SIFT tolerated (0.96); PolyPhen benign (0.003); catalogued as rs1409277212; called by muse, mutect2, varscan2
- SAMSN1 | c.945del p.E316Sfs*5 | Frame Shift Del (DEL) | VAF 84/270 reads (31%) | catalogued as COSV53473261; called by mutect2, pindel, varscan2
- SASS6 | c.599C>T p.A200V | Missense Mutation (SNP) | VAF 57/203 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.105); catalogued as rs887977995, COSV54926483; called by muse, mutect2, varscan2
- SBF1 | c.286A>G p.T96A | Missense Mutation (SNP) | VAF 72/225 reads (32%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as rs1486703093; called by muse, mutect2, varscan2
- SCAI | c.1784G>A p.R595Q (on ENST00000336505 / NM_001144877.3; = p.R618Q on NM_173690.5) | Missense Mutation (SNP) | VAF 98/259 reads (38%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.614); catalogued as rs541516222; called by muse, mutect2, varscan2
- SCRIB | c.3514G>A p.E1172K | Missense Mutation (SNP) | VAF 213/972 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs1281828169; called by muse, mutect2, varscan2
- SCRN2 | c.437del p.G146Afs*50 | Frame Shift Del (DEL) | VAF 136/435 reads (31%) | catalogued as rs750983392; called by mutect2, pindel, varscan2
- SEC14L1 | c.439del p.I147Lfs*3 | Frame Shift Del (DEL) | VAF 49/218 reads (22%) | catalogued as rs34381783; called by mutect2, pindel, varscan2
- SEC16B | c.2939del p.G980Vfs*44 | Frame Shift Del (DEL) | VAF 95/350 reads (27%) | catalogued as rs1327850557; called by mutect2, pindel, varscan2
- SEC23A | c.799G>A p.A267T | Missense Mutation (SNP) | VAF 82/288 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV56974470, COSV56979734; called by muse, varscan2
- SEMA3F | c.2167C>T p.P723S | Missense Mutation (SNP) | VAF 154/441 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.021); catalogued as COSV50028264; called by muse, mutect2, varscan2
- SEMA6B | c.2197del p.R733Afs*97 | Frame Shift Del (DEL) | VAF 132/624 reads (21%) | catalogued as rs1463047419; called by pindel, varscan2
- SETD1A | c.4301del p.G1434Afs*7 | Frame Shift Del (DEL) | VAF 128/353 reads (36%) | catalogued as COSV99352822; called by mutect2, pindel, varscan2
- SETD1B | c.4283G>A p.R1428Q | Missense Mutation (SNP) | VAF 152/440 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs756584620; called by muse, varscan2
- SETDB1 | c.1028G>A p.R343H | Missense Mutation (SNP) | VAF 111/397 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54992937; called by muse, mutect2, varscan2
- SFR1 | c.535T>C p.Y179H (on ENST00000369727 / NM_001002759.1; = p.Y166H on NM_145247.4) | Missense Mutation (SNP) | VAF 59/185 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777998701; called by muse, mutect2, varscan2
- SH3BP5L | c.1130G>T p.G377V | Missense Mutation (SNP) | VAF 150/458 reads (33%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.006); catalogued as COSV63540198; called by muse, mutect2, varscan2
- SHCBP1L | c.1017del p.K339Nfs*5 | Frame Shift Del (DEL) | VAF 50/249 reads (20%) | catalogued as rs756742767; called by mutect2, pindel, varscan2
- SHISA2 | c.752C>T p.T251M | Missense Mutation (SNP) | VAF 177/626 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.168); catalogued as rs766262628, COSV60110490; called by muse, mutect2, varscan2
2,282 further variants in this file (1,487 protein-altering or splice-affecting, 669 silent, 126 other) are not listed here.
